Somatic mutation profile of tumor specimen TCGA-D1-A1NY-01A (aliquot TCGA-D1-A1NY-01A-11D-A16D-09) from TCGA case TCGA-D1-A1NY, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IB; Tumor grade: G3; Age at diagnosis: 67.6 years (24,683 days).
Specimen TCGA-D1-A1NY-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 19b384e9-872e-4930-85f0-c43abf5df799.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-D1-A1NY-10A (Blood Derived Normal), aliquot TCGA-D1-A1NY-10A-01D-A16D-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a286f58d-5ce8-4633-9cab-69ecdfa341e1

The open-access MAF lists 703 somatic variants for this specimen: 546 protein-altering or splice-affecting, 141 silent, 16 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 338, Silent 141, Frame Shift Del 127, Frame Shift Ins 33, Nonsense Mutation 25, Splice Site 9, In Frame Del 8, Intron 6, Splice Region 6, 3'Flank 4, RNA 4, 5'Flank 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AMT | c.59dup p.A21Gfs*7 | Frame Shift Ins (INS) | VAF 8/24 reads (33%) | catalogued as rs386833686; ClinVar: uncertain significance / likely pathogenic; called by mutect2, pindel, varscan2
- ASXL1 | c.1934del p.G645Vfs*58 | Frame Shift Del (DEL) | VAF 14/36 reads (39%) | hotspot (GDC flag); catalogued as rs750318549; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- CWC27 | c.1002del p.V335* | Frame Shift Del (DEL) | VAF 7/33 reads (21%) | catalogued as rs752159903; ClinVar: pathogenic; called by mutect2, varscan2
- FGFR2 | c.755C>G p.S252W | Missense Mutation (SNP) | VAF 18/54 reads (33%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs79184941, CM950458, CM970526, COSV60638319; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- KMT2D | c.7933C>T p.R2645* | Nonsense Mutation (SNP) | VAF 28/52 reads (54%) | catalogued as rs1555191740, CM111915, COSV56409935; ClinVar: pathogenic; called by muse, mutect2, varscan2
- LRP2 | c.13139del p.P4380Hfs*46 | Frame Shift Del (DEL) | VAF 6/24 reads (25%) | catalogued as rs80338754; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- MAGEL2 | c.1996del p.Q666Sfs*36 | Frame Shift Del (DEL) | VAF 10/23 reads (43%) | catalogued as rs770374710, CD1510958; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- MFRP | c.3del p.H2Tfs*100 (on ENST00000449574; = p.H384Tfs*94 on NM_031433.4) | Frame Shift Del (DEL) | VAF 10/16 reads (63%) | catalogued as rs587776595; ClinVar: pathogenic; called by mutect2, varscan2
- OFD1 | c.710del p.K237Sfs*6 | Frame Shift Del (DEL) | VAF 39/76 reads (51%) | catalogued as rs312262845; ClinVar: pathogenic; called by mutect2, varscan2
- PIK3R1 | c.1746-19_1752delinsCAGTTTTGA p.X582_splice (on ENST00000521381 / NM_181523.3; = p.X312_splice on NM_181504.4) | Splice Site (DEL) | VAF 11/49 reads (22%) | hotspot (GDC flag); called by pindel, varscan2*
- RAD50 | c.2165del p.K722Rfs*14 | Frame Shift Del (DEL) | VAF 27/32 reads (84%) | catalogued as rs397507178, COSV54758496; ClinVar: pathogenic; called by mutect2, varscan2
- RBM39 | c.1058C>T p.T353I | Missense Mutation (SNP) | VAF 10/33 reads (30%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.84); catalogued as COSV53614904; called by muse, mutect2, varscan2
- TBCK | c.1370del p.N457Tfs*15 (on ENST00000273980 / NM_001163436.4; = p.N394Tfs*15 on NM_033115.5 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 18/54 reads (33%) | catalogued as rs746860249, CD164312; ClinVar: pathogenic; called by mutect2, varscan2
- A4GALT | c.364G>A p.A122T | Missense Mutation (SNP) | VAF 33/54 reads (61%) | SIFT tolerated (0.31); PolyPhen benign (0.019); catalogued as rs750440854, COSV99966581; called by muse, mutect2, varscan2
- AADACL4 | c.459G>T p.K153N | Missense Mutation (SNP) | VAF 28/86 reads (33%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.908); catalogued as COSV100879523, COSV66106258; called by muse, mutect2, varscan2
- ACD | c.784C>T p.R262W (on ENST00000620338; = p.R173W on NM_022914.3) | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.663); catalogued as rs758515562, COSV54667269; called by muse, mutect2, varscan2
- ACIN1 | c.3815A>G p.N1272S | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0); catalogued as COSV99400526; called by mutect2, varscan2
- ACTN1 | c.850A>G p.S284G | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.014); catalogued as COSV99518744; called by muse, mutect2, varscan2
- ACTR6 | c.1180T>A p.F394I | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV99498832; called by muse, mutect2, varscan2
- ACVR1 | c.154C>T p.Q52* | Nonsense Mutation (SNP) | VAF 3/45 reads (7%) | catalogued as COSV99718217; called by muse, mutect2
- ADA2 | c.512G>A p.R171Q | Missense Mutation (SNP) | VAF 9/86 reads (10%) | SIFT tolerated (0.75); PolyPhen benign (0.003); catalogued as rs1441421885; called by muse, mutect2, varscan2
- ADAM30 | c.1865del p.N622Ifs*71 | Frame Shift Del (DEL) | VAF 19/39 reads (49%) | catalogued as rs750058585; called by mutect2, varscan2
- ADD2 | c.1570A>G p.I524V | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as rs1553368407, COSV100036738; called by muse, varscan2
- ADD2 | c.1516A>G p.N506D | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV100036740; called by muse, varscan2
- AFAP1L1 | c.1168G>T p.A390S | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.787); catalogued as COSV99696216; called by muse, mutect2, varscan2
- AFF2 | c.881G>A p.G294D | Missense Mutation (SNP) | VAF 4/35 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100651483, COSV60676045; called by mutect2, varscan2
- AGXT2 | c.1264C>T p.R422W | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as rs553649751, COSV99183765; called by muse, mutect2, varscan2
- AK9 | c.5708_5709dup p.R1904Sfs*4 | Frame Shift Ins (INS) | VAF 15/59 reads (25%) | catalogued as rs1325930894; called by mutect2, varscan2
- AKAP8L | c.868A>G p.K290E | Missense Mutation (SNP) | VAF 17/40 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV101275902; called by muse, mutect2, varscan2
- AMDHD1 | c.524G>A p.R175H | Missense Mutation (SNP) | VAF 24/44 reads (55%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.912); catalogued as rs1178699284, COSV57140901; called by muse, mutect2, varscan2
- AMER2 | c.1748G>A p.R583Q | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.942); catalogued as rs756833733, COSV63437074, COSV63438592; called by muse, mutect2, varscan2
- ANKMY1 | c.1607G>A p.R536Q | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.765); catalogued as rs760526137, COSV56032798; called by muse, mutect2, varscan2
- ANKRD26 | c.500T>C p.L167S | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as COSV100772701; called by muse, mutect2, varscan2
- AOC3 | c.424G>C p.V142L | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT tolerated (0.1); PolyPhen benign (0.041); catalogued as COSV99520502; called by muse, mutect2, varscan2
- AOX1 | c.2458G>A p.V820I | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs756261449, COSV65980852; called by muse, mutect2, varscan2
- APBA3 | c.1235C>T p.S412L | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1488946377, COSV99516568; called by muse, mutect2, varscan2
- APEX2 | c.1471C>T p.R491C | Missense Mutation (SNP) | VAF 24/49 reads (49%) | SIFT tolerated (0.12); PolyPhen benign (0.013); catalogued as rs145264172, COSV100238741; called by muse, mutect2, varscan2
- ARAF | c.121G>A p.V41I | Missense Mutation (SNP) | VAF 17/37 reads (46%) | SIFT deleterious (0.02); PolyPhen benign (0.381); catalogued as COSV99283518; called by muse, mutect2, varscan2
- ARGLU1 | c.497G>A p.R166H | Missense Mutation (SNP) | VAF 38/122 reads (31%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.984); catalogued as rs1402870612, COSV62271387; called by muse, mutect2, varscan2
- ARHGAP28 | c.1291C>T p.Q431* (on ENST00000383472 / NM_001366230.1; = p.Q272* on NM_001010000.3) | Nonsense Mutation (SNP) | VAF 6/41 reads (15%) | catalogued as COSV99151670; called by muse, mutect2, varscan2
- ARHGAP9 | c.1588C>T p.Q530* (on ENST00000393797 / NM_001319850.2; = p.Q511* on NM_032496.4) | Nonsense Mutation (SNP) | VAF 14/25 reads (56%) | catalogued as COSV57359217; called by muse, mutect2, varscan2
- ARHGEF18 | c.1492A>G p.I498V (on ENST00000359920 / NM_001130955.2; = p.I394V on NM_015318.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 26/52 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.871); catalogued as COSV100148957; called by muse, mutect2, varscan2
- ARMC5 | c.1633G>A p.G545S | Missense Mutation (SNP) | VAF 3/10 reads (30%) | SIFT tolerated (0.74); PolyPhen benign (0.028); catalogued as rs963272909, COSV99192923; called by muse, mutect2
- ASB14 | c.1271C>A p.P424Q | Missense Mutation (SNP) | VAF 4/41 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101274281; called by mutect2, varscan2
- ASH2L | c.23C>A p.P8H | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.171); catalogued as COSV99167059; called by muse, mutect2, varscan2
- ASXL2 | c.2890A>G p.M964V | Missense Mutation (SNP) | VAF 34/84 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.035); catalogued as rs1179601924, COSV99712278; called by muse, mutect2, varscan2
- ATN1 | c.1441C>A p.H481N | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.001); catalogued as COSV100755998; called by muse, mutect2, varscan2
- ATP7B | c.3589G>A p.A1197T | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs758025913, CM994114, COSV54441279; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ATXN1 | c.2077G>T p.G693C | Missense Mutation (SNP) | VAF 3/44 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99788259; called by muse, mutect2
- ATXN10 | c.1195C>T p.P399S | Missense Mutation (SNP) | VAF 18/161 reads (11%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.447); catalogued as COSV99426146, COSV99426868; called by muse, mutect2, varscan2
- AUTS2 | c.875C>A p.P292H | Missense Mutation (SNP) | VAF 29/65 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.634); catalogued as COSV100719784; called by muse, mutect2, varscan2
- B4GALNT4 | c.2972del p.G991Vfs*71 | Frame Shift Del (DEL) | VAF 13/49 reads (27%) | catalogued as rs35951843; called by mutect2, pindel, varscan2
- BARHL1 | c.233T>C p.L78P | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0); catalogued as COSV99707764; called by muse, mutect2, varscan2
- BCORL1 | c.3110G>A p.R1037H | Missense Mutation (SNP) | VAF 23/46 reads (50%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0); catalogued as rs187190724, COSV99499609; called by muse, mutect2, varscan2
- BEST3 | c.355G>T p.E119* | Nonsense Mutation (SNP) | VAF 12/43 reads (28%) | catalogued as COSV99876450; called by muse, mutect2, varscan2
- BMS1 | c.3279C>T p.S1093= | Splice Region (SNP) | VAF 32/116 reads (28%) | catalogued as rs752119072, COSV65734349; called by muse, mutect2, varscan2
- C10orf62 | c.592_593dup p.F199Pfs*86 | Frame Shift Ins (INS) | VAF 5/22 reads (23%) | catalogued as rs1371494618; called by mutect2, varscan2
- C11orf24 | c.620T>C p.L207P | Missense Mutation (SNP) | VAF 34/81 reads (42%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as COSV100422774; called by muse, mutect2, varscan2
- C2orf68 | c.341C>T p.A114V | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.677); catalogued as COSV100108362, COSV60472619; called by muse, mutect2, varscan2
- C9orf72 | c.298G>A p.D100N | Missense Mutation (SNP) | VAF 32/73 reads (44%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.648); catalogued as COSV101186570; called by muse, mutect2, varscan2
- CACNG7 | c.614C>T p.A205V | Missense Mutation (SNP) | VAF 26/70 reads (37%) | SIFT tolerated (0.14); PolyPhen benign (0.121); catalogued as COSV99712386; called by muse, mutect2, varscan2
- CALCA | c.24dup p.F9Lfs*36 | Frame Shift Ins (INS) | VAF 17/56 reads (30%) | catalogued as rs1555026447; called by mutect2, pindel, varscan2
- CAMSAP2 | c.2880_2882del p.S961del (on ENST00000236925 / NM_001297707.2; = p.S950del on NM_203459.3) | In Frame Del (DEL) | VAF 8/35 reads (23%) | catalogued as rs1184027031; called by pindel, varscan2
- CAND2 | c.1192A>G p.T398A (on ENST00000456430 / NM_001162499.2; = p.T305A on NM_012298.3) | Missense Mutation (SNP) | VAF 24/44 reads (55%) | SIFT tolerated (0.85); PolyPhen benign (0); catalogued as rs1055702063, COSV99930006; called by muse, mutect2
- CASP5 | c.1096+1G>A p.X366_splice | Splice Site (SNP) | VAF 24/50 reads (48%) | catalogued as rs141481245; called by muse, mutect2
- CASP8AP2 | c.3182C>A p.S1061* | Nonsense Mutation (SNP) | VAF 5/8 reads (63%) | catalogued as rs1471516809, COSV99387681; called by muse, mutect2, varscan2
- CBX5 | c.122G>A p.W41* | Nonsense Mutation (SNP) | VAF 10/36 reads (28%) | catalogued as COSV52939221; called by muse, mutect2, varscan2
- CCAR2 | c.2477G>A p.R826Q | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.968); catalogued as COSV99374407; called by muse, mutect2, varscan2
- CCDC144A | c.1515G>T p.E505D | Missense Mutation (SNP) | VAF 51/155 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.009); catalogued as COSV100138770; called by muse, mutect2, varscan2
- CCDC15 | c.2783G>T p.G928V | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.014); catalogued as COSV100777107; called by mutect2, varscan2
- CCDC183 | c.146G>A p.R49H | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT tolerated (0.12); PolyPhen benign (0.01); catalogued as rs1461461863, COSV100565875; called by muse, mutect2, varscan2
- CCDC25 | c.102G>A p.W34* | Nonsense Mutation (SNP) | VAF 9/32 reads (28%) | catalogued as COSV100738363; called by muse, mutect2, varscan2
- CCDC43 | c.646del p.R216Gfs*20 | Frame Shift Del (DEL) | VAF 28/58 reads (48%) | catalogued as rs751135235; called by mutect2, varscan2
- CCDC69 | c.824C>T p.A275V | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.447); catalogued as rs150024530; called by muse, mutect2, varscan2
- CCHCR1 | c.2258A>G p.D753G | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99456398; called by muse, mutect2, varscan2
- CCSER1 | c.1940A>T p.D647V | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT tolerated (0.06); PolyPhen benign (0.262); catalogued as rs562246982, COSV100397455; called by muse, mutect2, varscan2
- CD4 | c.532G>T p.D178Y | Missense Mutation (SNP) | VAF 13/29 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1555117658, COSV99163979; called by muse, mutect2, varscan2
- CDH5 | c.1474G>A p.V492I | Missense Mutation (SNP) | VAF 15/58 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.072); catalogued as COSV100439522; called by muse, mutect2, varscan2
- CDH5 | c.1509A>G p.I503M | Missense Mutation (SNP) | VAF 29/66 reads (44%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.667); catalogued as COSV100439523; called by muse, mutect2, varscan2
- CDK12 | c.2312C>T p.A771V | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101420590; called by muse, mutect2, varscan2
- CDKAL1 | c.599G>A p.R200K | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.162); catalogued as COSV99216777; called by muse, mutect2, varscan2
- CEP152 | c.670_672del p.Q224del | In Frame Del (DEL) | VAF 28/67 reads (42%) | catalogued as rs764982977; called by pindel, varscan2
- CEP170B | c.1933del p.Q645Rfs*179 (on ENST00000453495; = p.Q574Rfs*179 on NM_015005.3) | Frame Shift Del (DEL) | VAF 23/55 reads (42%) | catalogued as rs1431118175; called by mutect2, pindel, varscan2
- CFAP251 | c.1139C>T p.A380V | Missense Mutation (SNP) | VAF 28/60 reads (47%) | SIFT tolerated (0.14); PolyPhen benign (0.046); catalogued as COSV99996595; called by muse, mutect2, varscan2
- CHD1L | c.1280G>A p.G427D | Missense Mutation (SNP) | VAF 25/53 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100787669; called by muse, mutect2, varscan2
- CHORDC1 | c.672G>A p.G224= | Splice Region (SNP) | VAF 5/24 reads (21%) | catalogued as rs1175540504, COSV100272215; called by muse, mutect2
- CHST5 | c.877G>A p.V293M | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.854); catalogued as COSV100292055, COSV100292179; called by muse, mutect2, varscan2
- CIRBP | c.74T>G p.V25G | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.561); catalogued as COSV100309926; called by muse, mutect2, varscan2
- CKAP5 | c.1579G>A p.A527T | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.984); catalogued as rs778951546, COSV100371599; called by muse, mutect2, varscan2
- CLCN1 | c.2689A>G p.T897A | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT tolerated (0.74); PolyPhen benign (0.003); catalogued as COSV100578690; called by muse, mutect2, varscan2
- CLCN4 | c.2266T>C p.S756P | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.062); catalogued as COSV101074125; called by muse, mutect2, varscan2
- CMTM1 | c.466G>A p.A156T (on ENST00000457188 / NM_181269.3; = p.A273T on NM_052999.4) | Missense Mutation (SNP) | VAF 22/48 reads (46%) | SIFT tolerated (0.51); PolyPhen benign (0.02); catalogued as rs1350186022, COSV99216622; called by muse, mutect2, varscan2
- CNTNAP1 | c.230T>C p.M77T | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT tolerated (0.21); PolyPhen benign (0.023); catalogued as rs144497813; called by muse, mutect2, varscan2
- COL19A1 | c.455A>G p.D152G | Missense Mutation (SNP) | VAF 6/63 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.057); catalogued as COSV100507804; called by muse, mutect2
- COL4A6 | c.4792T>C p.W1598R | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100565232; called by muse, mutect2, varscan2
- COL6A3 | c.3155A>G p.Q1052R | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT tolerated (0.35); PolyPhen benign (0.018); catalogued as COSV99802376; called by muse, mutect2, varscan2
- COLEC12 | c.1999G>A p.G667S | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV101232220; called by mutect2, varscan2
- CPT1A | c.1405C>A p.L469I | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT tolerated (0.39); PolyPhen benign (0.031); catalogued as COSV55760158; called by muse, mutect2, varscan2
- CR2 | c.971G>A p.R324H | Missense Mutation (SNP) | VAF 28/83 reads (34%) | SIFT tolerated (0.4); PolyPhen benign (0.006); catalogued as rs779099967, COSV65506828; called by muse, mutect2, varscan2
- CRACDL | c.706C>T p.R236W | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101194179; called by muse, mutect2, varscan2
- CRMP1 | c.622-1G>T p.X208_splice | Splice Site (SNP) | VAF 15/34 reads (44%) | catalogued as COSV100272511; called by muse, mutect2, varscan2
- CSGALNACT2 | c.653T>A p.F218Y | Missense Mutation (SNP) | VAF 13/25 reads (52%) | SIFT deleterious (0.01); PolyPhen benign (0.138); catalogued as COSV100989864; called by muse, mutect2, varscan2
- CSK | c.19G>A p.A7T | Missense Mutation (SNP) | VAF 28/66 reads (42%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as rs758951634, COSV99584001; called by muse, mutect2, varscan2
- CSRNP1 | c.386C>T p.A129V | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.242); catalogued as rs866090111, COSV56187387; called by muse, mutect2, varscan2
- CST8 | c.34C>A p.L12I | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT tolerated (0.07); PolyPhen benign (0.333); catalogued as COSV55671162, COSV99850137; called by muse, mutect2, varscan2
- CTNND1 | c.1556G>A p.R519H | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs758420026, COSV62383742; called by muse, mutect2, varscan2
- CTTNBP2NL | c.1292C>T p.P431L | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs768603831, COSV54745579; called by muse, mutect2, varscan2
- CWF19L2 | c.2084A>C p.K695T | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.574); catalogued as COSV99980195; called by muse, mutect2, varscan2
- CYP3A43 | c.553A>G p.T185A | Missense Mutation (SNP) | VAF 35/85 reads (41%) | SIFT tolerated (0.13); PolyPhen benign (0.013); catalogued as COSV99733767; called by muse, mutect2, varscan2
- DAPK1 | c.453T>A p.N151K | Missense Mutation (SNP) | VAF 21/45 reads (47%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.495); catalogued as rs1255711123, COSV100802935; called by muse, mutect2, varscan2
- DDR1 | c.1552G>A p.A518T | Missense Mutation (SNP) | VAF 21/63 reads (33%) | SIFT tolerated (0.56); PolyPhen benign (0.091); catalogued as COSV100242280; called by muse, mutect2, varscan2
- DHX16 | c.3032T>C p.V1011A | Missense Mutation (SNP) | VAF 8/70 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.306); catalogued as COSV99528261; called by muse, mutect2
- DIP2B | c.706C>T p.R236C | Missense Mutation (SNP) | VAF 21/82 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.714); catalogued as rs759010576, COSV99999695; called by muse, mutect2, varscan2
- DISP1 | c.1804C>T p.Q602* | Nonsense Mutation (SNP) | VAF 21/72 reads (29%) | catalogued as rs555036894, COSV99452451; called by muse, mutect2, varscan2
- DLL1 | c.1648G>A p.A550T | Missense Mutation (SNP) | VAF 16/33 reads (48%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.638); catalogued as rs961819995, COSV100816228; called by muse, mutect2, varscan2
- DLL1 | c.1462G>A p.A488T | Missense Mutation (SNP) | VAF 3/14 reads (21%) | SIFT tolerated (0.25); PolyPhen benign (0.164); catalogued as rs768701175, COSV100816230, COSV64537966; called by muse, mutect2
- DNAH7 | c.11365A>G p.M3789V | Missense Mutation (SNP) | VAF 32/73 reads (44%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs759689589, COSV100418190; called by muse, mutect2, varscan2
- DNAH7 | c.11026G>A p.D3676N | Missense Mutation (SNP) | VAF 21/48 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.969); catalogued as rs746243860, COSV100418192; called by muse, mutect2, varscan2
- DNAH7 | c.9853del p.C3285Vfs*2 | Frame Shift Del (DEL) | VAF 10/41 reads (24%) | catalogued as COSV100414357; called by mutect2, pindel, varscan2
- DOCK2 | c.4463C>T p.S1488L | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT tolerated (0.17); PolyPhen benign (0.145); catalogued as rs149796867; called by muse, mutect2, varscan2
- DPYSL5 | c.1408A>G p.T470A | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT deleterious (0.05); PolyPhen benign (0.003); catalogued as COSV99982917; called by muse, mutect2, varscan2
- DSG1 | c.1821G>T p.R607S | Missense Mutation (SNP) | VAF 29/85 reads (34%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as rs1285854431, COSV99936723; called by muse, mutect2, varscan2
- DST | c.12479T>C p.L4160P (on ENST00000361203 / NM_001374722.1; = p.L1748P on NM_015548.5) | Missense Mutation (SNP) | VAF 22/51 reads (43%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.984); catalogued as COSV99761060; called by muse, mutect2, varscan2
- DYNC2I2 | c.743G>A p.S248N | Missense Mutation (SNP) | VAF 19/48 reads (40%) | SIFT deleterious (0.04); PolyPhen benign (0.027); catalogued as rs777232958, COSV100824138; called by muse, mutect2, varscan2
- E2F8 | c.2473C>T p.R825C | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs375220543, COSV51462201; called by muse, mutect2, varscan2
- EDRF1 | c.2837C>T p.A946V (on ENST00000356792 / NM_001202438.2; = p.A912V on NM_015608.2) | Missense Mutation (SNP) | VAF 19/51 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs758980140, COSV100524150; called by muse, mutect2, varscan2
- EFHB | c.1165G>A p.A389T | Missense Mutation (SNP) | VAF 21/55 reads (38%) | SIFT tolerated (0.48); PolyPhen benign (0.003); catalogued as COSV99860381; called by muse, varscan2
- EI24 | c.176G>T p.R59L | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT tolerated (0.11); PolyPhen benign (0.223); catalogued as COSV99628993, COSV99629282; called by muse, varscan2
- EIF2AK2 | c.1642C>T p.R548* | Nonsense Mutation (SNP) | VAF 25/72 reads (35%) | catalogued as rs191011347, COSV51799352; called by muse, mutect2, varscan2
- ELAPOR1 | c.563C>T p.T188I | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT tolerated (0.15); PolyPhen benign (0.284); catalogued as rs766286896, COSV100884793; called by mutect2, varscan2
- ELL3 | c.1016G>C p.R339P | Missense Mutation (SNP) | VAF 21/46 reads (46%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as COSV100082710; called by muse, mutect2, varscan2
- EPAS1 | c.79C>T p.R27W | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99763796; called by muse, mutect2, varscan2
- EPHA6 | c.1191C>A p.Y397* | Nonsense Mutation (SNP) | VAF 21/52 reads (40%) | catalogued as COSV101061726; called by muse, mutect2, varscan2
- EPPK1 | c.182T>C p.M61T | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT tolerated (0.41); PolyPhen benign (0.018); catalogued as COSV73262418; called by muse, mutect2, varscan2
- ERCC6L2 | c.471G>T p.Q157H | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV56632779; called by muse, mutect2, varscan2
- EXOC1 | c.2441A>C p.K814T | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.758); catalogued as COSV100638082; called by muse, mutect2, varscan2
- FAM118B | c.452A>G p.H151R | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT tolerated (0.86); PolyPhen benign (0.01); catalogued as COSV100796941; called by muse, mutect2, varscan2
- FAT4 | c.14701G>T p.E4901* | Nonsense Mutation (SNP) | VAF 8/21 reads (38%) | catalogued as COSV58694001, COSV58699757; called by muse, mutect2, varscan2
- FDXR | c.844C>T p.R282* (on ENST00000293195 / NM_024417.5; = p.R288* on NM_004110.6) | Nonsense Mutation (SNP) | VAF 10/22 reads (45%) | catalogued as rs760046738, COSV53110797; called by muse, mutect2
- FER1L6 | c.2332G>C p.D778H | Missense Mutation (SNP) | VAF 17/48 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101205991, COSV101206251; called by muse, mutect2, varscan2
- FETUB | c.437del p.K146Rfs*4 | Frame Shift Del (DEL) | VAF 11/21 reads (52%) | catalogued as rs748969702; called by mutect2, varscan2
- FFAR3 | c.587C>T p.P196L | Missense Mutation (SNP) | VAF 18/98 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs780541841, COSV59909027; called by muse, mutect2, varscan2
- FNDC3A | c.2044C>T p.R682* (on ENST00000492622 / NM_001079673.2; = p.R626* on NM_014923.5) | Nonsense Mutation (SNP) | VAF 6/12 reads (50%) | catalogued as COSV101256854; called by muse, mutect2, varscan2
- FOXA1 | c.263dup p.S89Lfs*138 | Frame Shift Ins (INS) | VAF 5/12 reads (42%) | catalogued as rs766493600; called by mutect2, varscan2
- FOXD4L3 | c.124G>A p.E42K | Missense Mutation (SNP) | VAF 19/143 reads (13%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.115); catalogued as rs1396399535; called by muse, mutect2, varscan2
- FOXG1 | c.800G>A p.G267D | Missense Mutation (SNP) | VAF 20/51 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100487141; called by muse, mutect2, varscan2
- FRMD8 | c.763C>T p.R255C | Missense Mutation (SNP) | VAF 8/17 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as rs774787597, COSV100454931; called by muse, varscan2
- FSCN3 | c.869G>A p.R290H | Missense Mutation (SNP) | VAF 19/52 reads (37%) | SIFT tolerated (0.46); PolyPhen benign (0.005); catalogued as rs139784096; called by muse, mutect2, varscan2
- FYCO1 | c.4366G>T p.V1456F | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.494); catalogued as COSV99946409; called by muse, mutect2, varscan2
- GABBR1 | c.829C>T p.R277W | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as rs773510557, COSV100590199; called by muse, mutect2, varscan2
- GALNT13 | c.590C>T p.A197V | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT tolerated (0.16); PolyPhen benign (0.041); catalogued as COSV67217027; called by muse, mutect2, varscan2
- GAS2 | c.550C>T p.P184S | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT tolerated (0.25); PolyPhen benign (0.039); catalogued as rs761221779, COSV99535902; called by muse, mutect2, varscan2
- GAS8 | c.431C>T p.A144V | Missense Mutation (SNP) | VAF 16/28 reads (57%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as COSV99244291; called by muse, mutect2, varscan2
- GDF6 | c.1055T>C p.L352P | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT tolerated (0.27); PolyPhen benign (0.161); catalogued as COSV54622920; called by muse, mutect2, varscan2
- GDNF | c.547G>A p.A183T | Missense Mutation (SNP) | VAF 50/110 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.985); catalogued as rs775792714, COSV100427610; called by muse, mutect2, varscan2
- GDPD5 | c.474+1G>A p.X158_splice | Splice Site (SNP) | VAF 21/60 reads (35%) | catalogued as COSV100409570; called by muse, mutect2, varscan2
- GIGYF1 | c.331del p.L111Wfs*234 | Frame Shift Del (DEL) | VAF 12/25 reads (48%) | catalogued as rs763147690; called by mutect2, varscan2
- GIMAP6 | c.430A>T p.R144W | Missense Mutation (SNP) | VAF 13/29 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV100188426; called by muse, mutect2, varscan2
- GLB1L2 | c.1739G>A p.G580D | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.799); catalogued as COSV56996786; called by muse, mutect2, varscan2
- GLMP | c.646T>C p.C216R | Missense Mutation (SNP) | VAF 16/23 reads (70%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.525); catalogued as COSV99828200; called by muse, mutect2, varscan2
- GOLGA3 | c.4007A>C p.Q1336P | Missense Mutation (SNP) | VAF 4/51 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.719); catalogued as COSV99213262; called by mutect2, varscan2
- GOPC | c.1364C>G p.T455S | Missense Mutation (SNP) | VAF 22/47 reads (47%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV99271504; called by muse, mutect2, varscan2
- GOT1L1 | c.1243del p.T415Hfs*2 | Frame Shift Del (DEL) | VAF 17/53 reads (32%) | catalogued as rs370114090; called by mutect2, varscan2
- GPER1 | c.910del p.L304Sfs*16 | Frame Shift Del (DEL) | VAF 18/59 reads (31%) | catalogued as rs776379860; called by mutect2, pindel, varscan2
- GPR158 | c.1228G>A p.V410I | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT tolerated (0.31); PolyPhen benign (0.206); catalogued as rs757293544, COSV66267946; called by muse, mutect2, varscan2
- GPRASP1 | c.61G>C p.E21Q | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.401); catalogued as COSV100851110, COSV64355581; called by mutect2, varscan2
- GPRIN2 | c.55C>T p.Q19* | Nonsense Mutation (SNP) | VAF 12/41 reads (29%) | catalogued as COSV100966520; called by muse, mutect2, varscan2
- GRID2 | c.2671C>A p.P891T | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.487); catalogued as COSV99948310; called by muse, mutect2, varscan2
- GTDC1 | c.1007A>G p.K336R | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT tolerated (0.33); PolyPhen benign (0.023); catalogued as COSV99602227; called by muse, mutect2, varscan2
- HABP2 | c.641C>T p.A214V | Missense Mutation (SNP) | VAF 26/65 reads (40%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as rs529346597, COSV63637721; called by muse, mutect2, varscan2
- HDGFL3 | c.181G>A p.D61N | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); catalogued as COSV100220985; called by muse, mutect2, varscan2
- HECTD4 | c.13018C>T p.R4340C | Missense Mutation (SNP) | VAF 27/71 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs767002103, COSV66395665; called by muse, mutect2, varscan2
- HERC2 | c.14200G>A p.A4734T | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as rs1175518080, COSV55312027; called by muse, mutect2, varscan2
- HGFAC | c.1802C>A p.P601H | Missense Mutation (SNP) | VAF 11/73 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101237790; called by muse, mutect2, varscan2
- HK1 | c.1919C>T p.A640V | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.44); catalogued as COSV100068219, COSV53856223; called by muse, mutect2, varscan2
- HMCN1 | c.6584del p.P2195Qfs*44 | Frame Shift Del (DEL) | VAF 13/34 reads (38%) | catalogued as COSV99636186; called by mutect2, pindel, varscan2
- HTR1A | c.392C>T p.A131V | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60503279; called by muse, mutect2, varscan2
- HTR5A | c.487G>A p.A163T | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT tolerated (0.16); PolyPhen benign (0.015); catalogued as rs1253257729, COSV55281066, COSV55283141; called by muse, mutect2, varscan2
- IDH2 | c.435del p.T146Lfs*15 | Frame Shift Del (DEL) | VAF 27/62 reads (44%) | catalogued as rs747216375; ClinVar: uncertain significance; called by mutect2, pindel, varscan2
- IFNLR1 | c.1132G>A p.E378K | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT tolerated (0.13); PolyPhen benign (0.005); catalogued as rs772933526, COSV59527674; called by muse, mutect2, varscan2
- IFT80 | c.1597T>C p.Y533H | Missense Mutation (SNP) | VAF 26/58 reads (45%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.819); catalogued as COSV100425217; called by muse, mutect2, varscan2
- IGFN1 | c.1636A>G p.I546V (on ENST00000295591 / NM_001367841.1; = p.I3003V on NM_001164586.2) | Missense Mutation (SNP) | VAF 31/60 reads (52%) | SIFT tolerated (0.77); PolyPhen benign (0.074); catalogued as COSV99811009; called by muse, mutect2, varscan2
- IKBKB | c.955A>G p.T319A | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT tolerated (0.12); PolyPhen benign (0.044); catalogued as COSV100645884; called by muse, mutect2, varscan2
- IL3RA | c.432-1G>A p.X144_splice | Splice Site (SNP) | VAF 31/92 reads (34%) | catalogued as rs757765898, COSV58429746; called by muse, mutect2, varscan2
- INSM2 | c.1605dup p.S536* | Frame Shift Ins (INS) | VAF 8/44 reads (18%) | catalogued as rs756928018; called by mutect2, varscan2
- INTS11 | c.1030G>A p.E344K | Missense Mutation (SNP) | VAF 21/40 reads (53%) | SIFT tolerated (0.06); PolyPhen benign (0.21); catalogued as COSV60090642; called by muse, mutect2, varscan2
- INTS4 | c.833G>A p.R278H | Missense Mutation (SNP) | VAF 61/177 reads (34%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.964); catalogued as rs765120138, COSV101417186, COSV71087626; called by muse, mutect2, varscan2
- IQGAP2 | c.1406C>T p.P469L | Missense Mutation (SNP) | VAF 26/52 reads (50%) | SIFT tolerated (0.15); PolyPhen benign (0.007); catalogued as COSV99169320; called by muse, mutect2, varscan2
- IRS4 | c.584G>T p.S195I | Missense Mutation (SNP) | VAF 8/14 reads (57%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.794); catalogued as COSV100929840; called by muse, mutect2, varscan2
- ISLR2 | c.1766C>T p.S589L | Missense Mutation (SNP) | VAF 11/21 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as COSV100679844; called by muse, mutect2, varscan2
- ITPKC | c.1807C>T p.R603C | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.314); catalogued as rs904288189, COSV54573896; called by muse, mutect2, varscan2
- JHY | c.326A>T p.D109V | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT tolerated (0.17); PolyPhen benign (0.07); catalogued as COSV99913956; called by mutect2, varscan2
- JMY | c.2720A>G p.K907R | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as rs1183635393, COSV101268142; called by muse, mutect2, varscan2
- KBTBD3 | c.1190C>T p.T397I | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.471); catalogued as COSV101595737; called by muse, mutect2, varscan2
- KCNMA1 | c.2306del p.K769Sfs*17 (on ENST00000286628 / NM_001161352.2; = p.K711Sfs*17 on NM_002247.4) | Frame Shift Del (DEL) | VAF 32/130 reads (25%) | catalogued as rs771351714; called by mutect2, varscan2
- KCNQ1 | c.1519C>T p.R507W | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.948); catalogued as rs767882075, COSV99328927; called by muse, mutect2, varscan2
- KIAA0319L | c.2305G>A p.A769T | Missense Mutation (SNP) | VAF 32/76 reads (42%) | SIFT deleterious (0.03); PolyPhen benign (0.078); catalogued as rs773278050, COSV100357827; called by muse, mutect2, varscan2
- KIAA0408 | c.1822C>T p.L608F | Missense Mutation (SNP) | VAF 37/91 reads (41%) | SIFT tolerated (0.08); PolyPhen benign (0.039); catalogued as rs1378798080, COSV100847114; called by muse, mutect2, varscan2
- KIF7 | c.2156T>C p.M719T | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.118); catalogued as rs777546530, COSV67998219; called by muse, mutect2, varscan2
- KLHL41 | c.215del p.K72Rfs*3 | Frame Shift Del (DEL) | VAF 7/28 reads (25%) | catalogued as COSV52930337; called by mutect2, varscan2
- KNDC1 | c.1720G>A p.A574T | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.984); catalogued as COSV100466570; called by muse, mutect2, varscan2
- LAMA1 | c.185G>A p.R62Q | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as rs376345144; called by muse, mutect2, varscan2
- LAMA3 | c.2083A>G p.M695V | Missense Mutation (SNP) | VAF 41/113 reads (36%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as COSV100556061; called by muse, mutect2, varscan2
- LGALS9 | c.904C>T p.R302C (on ENST00000395473 / NM_009587.3; = p.R270C on NM_002308.4) | Missense Mutation (SNP) | VAF 22/56 reads (39%) | SIFT tolerated (0.08); PolyPhen benign (0.202); catalogued as rs199922464, COSV100119571; called by muse, mutect2, varscan2
- LGR6 | c.1154G>A p.R385H (on ENST00000367278 / NM_001017403.1; = p.R333H on NM_021636.3) | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT tolerated (0.17); PolyPhen benign (0.015); catalogued as rs527790135, COSV99708095; called by muse, varscan2
- LMTK2 | c.2993A>G p.D998G | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV99808052; called by muse, mutect2, varscan2
- LRFN3 | c.401G>A p.R134H | Missense Mutation (SNP) | VAF 5/9 reads (56%) | SIFT tolerated (0.28); PolyPhen benign (0.315); catalogued as rs1345568033, COSV55817048; called by muse, mutect2, varscan2
- LRP2 | c.86A>G p.D29G | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT tolerated (0.56); PolyPhen benign (0.003); catalogued as COSV99790783; called by muse, mutect2, varscan2
- LRRC49 | c.1991C>T p.A664V | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.917); catalogued as COSV53016959; called by muse, mutect2, varscan2
- LRRC4C | c.466C>T p.R156* | Nonsense Mutation (SNP) | VAF 12/30 reads (40%) | catalogued as COSV53426135; called by muse, mutect2, varscan2
- LRRFIP2 | c.938C>G p.A313G | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT deleterious (0.04); PolyPhen benign (0.35); catalogued as COSV100368777; called by muse, mutect2, varscan2
- LRRIQ3 | c.414del p.G139Dfs*20 | Frame Shift Del (DEL) | VAF 17/66 reads (26%) | catalogued as rs749244073; called by mutect2, pindel, varscan2
- MAGEA8 | c.808G>A p.V270M | Missense Mutation (SNP) | VAF 7/70 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.638); catalogued as COSV99674872; called by muse, mutect2, varscan2
- MAGEB6 | c.580G>A p.A194T | Missense Mutation (SNP) | VAF 19/43 reads (44%) | SIFT tolerated (0.14); PolyPhen benign (0.006); catalogued as COSV100983901; called by muse, mutect2, varscan2
- MAGED2 | c.1276C>A p.L426M | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99514823; called by muse, mutect2, varscan2
- MAGI3 | c.2470G>A p.A824T | Missense Mutation (SNP) | VAF 19/28 reads (68%) | SIFT tolerated (0.21); PolyPhen benign (0.006); catalogued as COSV100290753; called by muse, mutect2, varscan2
- MARCHF5 | c.509G>A p.R170H | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.109); catalogued as rs757883961, COSV62769804; called by muse, mutect2, varscan2
- MATN2 | c.1516T>G p.F506V | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.437); catalogued as COSV99647363; called by muse, mutect2
- MED12 | c.5972T>C p.L1991P | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.8); catalogued as COSV100380409; called by muse, mutect2, varscan2
- MEN1 | c.1424C>A p.P475Q | Missense Mutation (SNP) | VAF 5/8 reads (63%) | SIFT tolerated (0.9); PolyPhen benign (0.005); catalogued as COSV53648857; called by muse, varscan2
- MFSD9 | c.1326del p.S443Afs*6 | Frame Shift Del (DEL) | VAF 19/50 reads (38%) | catalogued as rs769987847; called by mutect2, pindel, varscan2
- MGAT3 | c.266C>T p.A89V | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT tolerated, low confidence (0.53); PolyPhen benign (0.148); catalogued as rs1289484379, COSV57865154; called by muse, mutect2, varscan2
- MIDEAS | c.939dup p.N314Qfs*38 | Frame Shift Ins (INS) | VAF 8/22 reads (36%) | catalogued as rs762448666; called by mutect2, varscan2
- MINK1 | c.1511T>C p.L504P | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.69); catalogued as COSV100767327; called by muse, mutect2, varscan2
- MLLT1 | c.1066G>T p.V356L | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as COSV99398352; called by muse, mutect2, varscan2
- MLPH | c.31A>G p.T11A | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.664); catalogued as COSV52818872; called by muse, mutect2, varscan2
- MRI1 | c.988del p.H330Tfs*24 (on ENST00000040663 / NM_001031727.4; = p.H283Tfs*24 on NM_032285.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 13/46 reads (28%) | catalogued as rs751646149; called by mutect2, pindel, varscan2
- MTARC2 | c.698T>C p.M233T | Missense Mutation (SNP) | VAF 7/69 reads (10%) | SIFT tolerated (0.2); PolyPhen benign (0.038); catalogued as COSV100831099; called by muse, mutect2, varscan2
- MTF1 | c.953A>G p.H318R | Missense Mutation (SNP) | VAF 51/126 reads (40%) | SIFT tolerated (0.55); PolyPhen benign (0.001); catalogued as COSV100888724; called by muse, mutect2, varscan2
- MTMR9 | c.584del p.N195Mfs*4 | Frame Shift Del (DEL) | VAF 14/32 reads (44%) | catalogued as rs767880823; called by mutect2, varscan2
- MTO1 | c.1348G>T p.G450* (on ENST00000370300 / NM_133645.3; = p.G425* on NM_012123.4) | Nonsense Mutation (SNP) | VAF 37/72 reads (51%) | catalogued as COSV100940285, COSV100940591; called by muse, mutect2, varscan2
- MYBPC2 | c.1962G>T p.W654C | Missense Mutation (SNP) | VAF 6/80 reads (8%) | SIFT tolerated (0.21); PolyPhen benign (0.021); catalogued as COSV100732057; called by muse, mutect2
- MYC | c.868C>A p.P290T (on ENST00000377970; = p.P305T on NM_002467.6) | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT tolerated (0.35); PolyPhen probably damaging (0.998); catalogued as COSV104388343, COSV99422043; called by muse, mutect2, varscan2
- NAALAD2 | c.1832A>G p.Q611R | Missense Mutation (SNP) | VAF 11/24 reads (46%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV100428952; called by muse, mutect2, varscan2
- NAALADL1 | c.1309C>T p.R437C | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100368322; called by muse, mutect2, varscan2
- NBEA | c.3362del p.N1121Mfs*9 | Frame Shift Del (DEL) | VAF 8/24 reads (33%) | catalogued as rs763376147; called by mutect2, varscan2
- NCKIPSD | c.172-3dup | Splice Region (INS) | VAF 12/31 reads (39%) | catalogued as rs768132931; called by mutect2, varscan2
- NFATC1 | c.451T>C p.S151P | Missense Mutation (SNP) | VAF 24/47 reads (51%) | SIFT tolerated (0.37); PolyPhen benign (0.003); catalogued as COSV99502786; called by muse, mutect2, varscan2
- NFRKB | c.3260C>T p.T1087M (on ENST00000446488 / NM_001143835.2; = p.T1112M on NM_006165.3) | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as rs1239362961, COSV58760175; called by muse, mutect2, varscan2
- NIPA2 | c.634del p.V212Cfs*12 | Frame Shift Del (DEL) | VAF 4/38 reads (11%) | catalogued as COSV57414103; called by mutect2, pindel
- NISCH | c.3125G>A p.R1042H | Missense Mutation (SNP) | VAF 24/52 reads (46%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs748520977, COSV61900909; called by muse, mutect2, varscan2
- NKPD1 | c.2372C>T p.P791L | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT tolerated, low confidence (0.54); PolyPhen benign (0.031); catalogued as rs752661219, COSV55524558; called by muse, mutect2, varscan2
- NKX3-2 | c.668G>A p.R223H | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs376860038; called by muse, mutect2, varscan2
- NLRP10 | c.613T>C p.Y205H | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV100150033; called by muse, mutect2, varscan2
- NOC4L | c.1462C>T p.P488S | Missense Mutation (SNP) | VAF 19/49 reads (39%) | SIFT tolerated (0.41); PolyPhen benign (0.001); catalogued as COSV100400286; called by muse, mutect2, varscan2
- NOTCH1 | c.5722G>A p.A1908T | Missense Mutation (SNP) | VAF 34/78 reads (44%) | SIFT tolerated (0.09); PolyPhen benign (0.339); catalogued as COSV99492714; called by muse, mutect2, varscan2
- NOTCH1 | c.2830G>A p.E944K | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT tolerated (0.42); PolyPhen possibly damaging (0.506); catalogued as COSV53095693, COSV99492719; called by muse, mutect2, varscan2
- NPAT | c.631C>T p.R211C | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99586447; called by muse, mutect2, varscan2
- NPHS1 | c.3274C>T p.R1092C | Missense Mutation (SNP) | VAF 15/37 reads (41%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.451); catalogued as rs199646631, COSV62288942; called by muse, mutect2, varscan2
- NPM1 | c.549_551del p.D183del | In Frame Del (DEL) | VAF 15/48 reads (31%) | catalogued as rs770452718; called by pindel, varscan2
- NSMF | c.711-1G>T p.X237_splice (on ENST00000371475 / NM_001130969.3; = p.X235_splice on NM_015537.4) | Splice Site (SNP) | VAF 4/70 reads (6%) | catalogued as COSV99481725; called by muse, mutect2
- NT5C3B | c.163C>T p.R55* | Nonsense Mutation (SNP) | VAF 15/47 reads (32%) | catalogued as COSV53172651; called by muse, mutect2, varscan2
- NTRK1 | c.2323A>G p.K775E | Missense Mutation (SNP) | VAF 13/27 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.832); catalogued as COSV100693896; called by muse, mutect2, varscan2
- NUP160 | c.211A>G p.N71D | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated (0.52); PolyPhen benign (0.023); catalogued as COSV101021702; called by mutect2, varscan2
- NUP88 | c.932C>T p.A311V | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs563564141, COSV56702610, COSV56708095; called by muse, mutect2, varscan2
- NWD1 | c.3617G>A p.R1206Q | Missense Mutation (SNP) | VAF 35/76 reads (46%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as rs779146966, COSV100343964, COSV60338429; called by muse, mutect2, varscan2
- OBSL1 | c.1496T>C p.L499P | Missense Mutation (SNP) | VAF 27/77 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.905); catalogued as COSV54727175, COSV99217680; called by muse, mutect2, varscan2
- ODF3L2 | c.348G>A p.R116= | Splice Region (SNP) | VAF 35/70 reads (50%) | catalogued as COSV100205480; called by muse, mutect2, varscan2
- OR14C36 | c.581A>G p.E194G | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.405); catalogued as COSV100507692; called by muse, mutect2, varscan2
- OR2K2 | c.200C>T p.T67M (on ENST00000374428; = p.T38M on NM_205859.2) | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs369771602; called by muse, mutect2, varscan2
- OR4S2 | c.320G>A p.C107Y | Missense Mutation (SNP) | VAF 20/47 reads (43%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.885); catalogued as COSV100412866; called by muse, mutect2, varscan2
- OR51D1 | c.865G>A p.A289T | Missense Mutation (SNP) | VAF 24/70 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.925); catalogued as COSV100712445; called by muse, mutect2, varscan2
- OR5AR1 | c.415C>T p.Q139* | Nonsense Mutation (SNP) | VAF 12/41 reads (29%) | catalogued as rs1198159185, COSV57253250; called by muse, mutect2, varscan2
- OR5M1 | c.877C>T p.R293W | Missense Mutation (SNP) | VAF 23/58 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.082); catalogued as rs768719281, COSV101591625; called by muse, mutect2, varscan2
- OR8G1 | c.181T>C p.Y61H | Missense Mutation (SNP) | VAF 5/133 reads (4%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.078); catalogued as COSV100422723; called by muse, mutect2
- OR8S1 | c.445T>C p.W149R | Missense Mutation (SNP) | VAF 27/86 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1249878385, COSV100043822; called by muse, mutect2, varscan2
- OTUD7B | c.2304del p.Y769Tfs*59 | Frame Shift Del (DEL) | VAF 17/39 reads (44%) | catalogued as COSV64917254; called by mutect2, varscan2
- P4HB | c.947G>A p.R316H | Missense Mutation (SNP) | VAF 21/57 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs776010531, COSV100515951; called by muse, mutect2, varscan2
- PAPOLB | c.1461G>A p.M487I | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT tolerated (0.19); PolyPhen benign (0.097); catalogued as COSV101271653; called by muse, mutect2, varscan2
- PAPPA2 | c.5129A>G p.Q1710R | Missense Mutation (SNP) | VAF 21/70 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.542); catalogued as COSV100868819; called by muse, mutect2, varscan2
- PCDHA11 | c.2189C>T p.A730V | Missense Mutation (SNP) | VAF 15/56 reads (27%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.003); catalogued as COSV56502239; called by muse, mutect2, varscan2
- PCDHB11 | c.1994G>A p.G665D | Missense Mutation (SNP) | VAF 36/104 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.555); catalogued as rs782031586, COSV100697219; called by muse, mutect2, varscan2
- PCDHB2 | c.2337G>T p.Q779H | Missense Mutation (SNP) | VAF 8/70 reads (11%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.003); catalogued as COSV50569850, COSV99039327; called by muse, mutect2, varscan2
- PCDHGA1 | c.1778C>T p.A593V | Missense Mutation (SNP) | VAF 18/99 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.969); catalogued as rs754685144, COSV65297868; called by muse, mutect2, varscan2
- PCNX3 | c.5006C>T p.A1669V | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.36); catalogued as COSV100856732; called by muse, mutect2, varscan2
- PDGFB | c.640C>T p.R214* | Nonsense Mutation (SNP) | VAF 11/42 reads (26%) | catalogued as COSV58650417; called by muse, mutect2, varscan2
- PELO | c.859C>A p.H287N | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT tolerated (0.94); PolyPhen benign (0); catalogued as COSV99252373; called by muse, mutect2, varscan2
- PHACTR3 | c.437C>T p.T146M | Missense Mutation (SNP) | VAF 16/32 reads (50%) | SIFT tolerated (0.27); PolyPhen benign (0.072); catalogued as rs747934926, COSV63025654; called by muse, mutect2, varscan2
- PHKB | c.1139G>A p.G380D | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.737); catalogued as COSV100068928; called by muse, mutect2, varscan2
- PIK3CG | c.533G>A p.R178H | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV63245654, COSV63251231; called by muse, mutect2
- PIK3R1 | c.1670G>A p.R557Q (on ENST00000521381 / NM_181523.3; = p.R287Q on NM_181504.4) | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.349); catalogued as COSV57131637, COSV57133365, COSV99143544; called by muse, varscan2
- PITPNC1 | c.956G>A p.G319D | Missense Mutation (SNP) | VAF 3/22 reads (14%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.147); catalogued as COSV100083790; called by muse, mutect2
- PITRM1 | c.1352T>C p.I451T | Missense Mutation (SNP) | VAF 16/31 reads (52%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.786); catalogued as COSV99829842; called by muse, mutect2, varscan2
- PJA1 | c.68G>T p.R23M | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100824851; called by muse, mutect2, varscan2
- PLAAT4 | c.483del p.A162Rfs*56 | Frame Shift Del (DEL) | VAF 12/44 reads (27%) | catalogued as rs745860467; called by mutect2, varscan2
- PLEC | c.1771A>G p.N591D (on ENST00000322810 / NM_201380.4; = p.N481D on NM_000445.5) | Missense Mutation (SNP) | VAF 5/71 reads (7%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.725); catalogued as rs1208736369, COSV100520009; called by muse, mutect2
- PLEKHA7 | c.2405del p.F802Sfs*21 | Frame Shift Del (DEL) | VAF 32/58 reads (55%) | catalogued as rs1333390805, COSV63043367; called by mutect2, varscan2
- PLXNA4 | c.53T>G p.V18G | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as COSV100328033; called by muse, mutect2, varscan2
- POR | c.309G>T p.K103N | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV101203744; called by muse, mutect2, varscan2
- PPM1D | c.1535del p.N512Ifs*2 | Frame Shift Del (DEL) | VAF 8/18 reads (44%) | catalogued as rs763475304; called by mutect2, pindel, varscan2
- PPP2R3C | c.67del p.S23Vfs*5 | Frame Shift Del (DEL) | VAF 14/34 reads (41%) | catalogued as rs758484975; called by mutect2, varscan2
- PQBP1 | c.184C>T p.L62F | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV99504643; called by muse, mutect2, varscan2
- PRDX3 | c.223A>G p.T75A | Missense Mutation (SNP) | VAF 22/45 reads (49%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.878); catalogued as rs1338194647, COSV100045484; called by muse, mutect2, varscan2
- PRICKLE3 | c.567C>T p.C189= | Splice Region (SNP) | VAF 17/48 reads (35%) | catalogued as rs142882850, COSV100889963; called by muse, mutect2, varscan2
- PRKCSH | c.1349G>A p.G450D | Missense Mutation (SNP) | VAF 36/90 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99372055; called by muse, mutect2, varscan2
- PRKDC | c.383T>C p.L128P | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100043485; called by muse, varscan2
- PRKG2 | c.1526G>T p.C509F | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.149); catalogued as COSV100019807, COSV100020723; called by muse, mutect2, varscan2
- PRPF6 | c.2792G>C p.R931T | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as COSV99413096; called by muse, mutect2, varscan2
- PRXL2A | c.218del p.N73Mfs*4 | Frame Shift Del (DEL) | VAF 21/73 reads (29%) | catalogued as COSV64690809; called by mutect2, pindel, varscan2
- PSMB5 | c.589G>T p.V197F | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.428); catalogued as COSV100557433; called by muse, mutect2, varscan2
- PTEN | c.542T>C p.L181P | Missense Mutation (SNP) | VAF 16/33 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.816); catalogued as CD110169, CM043774, COSV100911535, COSV104426441; called by muse, mutect2, varscan2
- PTPN5 | c.1409dup p.L471Tfs*304 | Frame Shift Ins (INS) | VAF 12/30 reads (40%) | catalogued as rs761650832; called by mutect2, varscan2
- PWP1 | c.904-1G>T p.X302_splice | Splice Site (SNP) | VAF 25/79 reads (32%) | catalogued as COSV101338866; called by muse, mutect2, varscan2
- PXDNL | c.2788G>A p.G930R | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.529); catalogued as rs767952702, COSV100687172; called by muse, mutect2, varscan2
- PYCR2 | c.337C>T p.P113S | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as COSV100661582; called by muse, mutect2, varscan2
- PYHIN1 | c.423del p.K141Nfs*55 | Frame Shift Del (DEL) | VAF 4/20 reads (20%) | catalogued as rs758393003; called by mutect2, pindel
- RABGAP1L | c.2086G>A p.A696T | Missense Mutation (SNP) | VAF 10/71 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV99275216; called by muse, mutect2, varscan2
- RALGAPB | c.1142dup p.H382Tfs*2 | Frame Shift Ins (INS) | VAF 18/50 reads (36%) | catalogued as rs756557178; called by mutect2, varscan2
- RARS2 | c.1289C>T p.A430V | Missense Mutation (SNP) | VAF 28/60 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.793); catalogued as rs1171602787, COSV101057530; called by muse, mutect2, varscan2
- RBM26 | c.2181del p.K727Nfs*5 (on ENST00000438737 / NM_001366735.2; = p.K700Nfs*5 on NM_022118.5) | Frame Shift Del (DEL) | VAF 12/76 reads (16%) | catalogued as rs751690893; called by mutect2, varscan2
- RDH13 | c.802G>A p.A268T (on ENST00000415061 / NM_001145971.2; = p.A197T on NM_138412.4) | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs557873351, COSV52561159; called by muse, mutect2, varscan2
- REX1BD | c.223G>T p.G75C | Missense Mutation (SNP) | VAF 20/44 reads (45%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.01); catalogued as COSV100679060; called by muse, mutect2, varscan2
- RGL2 | c.551G>A p.R184Q | Missense Mutation (SNP) | VAF 14/28 reads (50%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.997); catalogued as rs138299795; called by muse, mutect2, varscan2
- RGS22 | c.1918G>A p.A640T | Missense Mutation (SNP) | VAF 22/55 reads (40%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs774013023, COSV62664363; called by muse, mutect2, varscan2
- RHOBTB2 | c.920del p.G307Afs*88 | Frame Shift Del (DEL) | VAF 7/19 reads (37%) | catalogued as rs753391613; called by mutect2, varscan2
- RIPOR3 | c.691C>T p.R231C | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs567479170, COSV50387435; called by muse, mutect2, varscan2
- RNF43 | c.1976del p.G659Vfs*41 | Frame Shift Del (DEL) | VAF 20/49 reads (41%) | catalogued as rs755128667, COSV68457540; called by mutect2, pindel, varscan2
- RNF44 | c.450C>A p.C150* | Nonsense Mutation (SNP) | VAF 13/28 reads (46%) | catalogued as COSV51270040, COSV99222033; called by muse, mutect2, varscan2
- RSPH3 | c.918G>T p.E306D (on ENST00000252655; = p.E164D on NM_031924.8) | Missense Mutation (SNP) | VAF 7/93 reads (8%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.532); catalogued as COSV99396673; called by muse, mutect2
- RTCB | c.54C>G p.N18K | Missense Mutation (SNP) | VAF 19/57 reads (33%) | SIFT tolerated (0.28); PolyPhen benign (0.028); catalogued as COSV53279703, COSV99322476; called by muse, mutect2, varscan2
- RTKN2 | c.1348del p.I450Lfs*67 | Frame Shift Del (DEL) | VAF 18/48 reads (38%) | catalogued as rs759252078; called by mutect2, varscan2
- RTL3 | c.180G>T p.E60D | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT tolerated (0.1); PolyPhen benign (0.012); catalogued as COSV100330192; called by muse, mutect2, varscan2
- RUSC2 | c.2063G>T p.R688M | Missense Mutation (SNP) | VAF 20/49 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.519); catalogued as COSV100770956; called by muse, mutect2, varscan2
- SAAL1 | c.1043-1G>A p.X348_splice | Splice Site (SNP) | VAF 18/49 reads (37%) | catalogued as COSV55516474; called by muse, mutect2, varscan2
- SALL2 | c.290G>A p.S97N | Missense Mutation (SNP) | VAF 14/31 reads (45%) | SIFT tolerated (0.45); PolyPhen benign (0.003); catalogued as COSV100444685; called by muse, mutect2, varscan2
- SAMD9 | c.341A>C p.Q114P | Missense Mutation (SNP) | VAF 6/130 reads (5%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.497); catalogued as COSV101180400; called by muse, mutect2
- SCAF4 | c.1715A>C p.Q572P | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.977); catalogued as COSV99742291; called by muse, mutect2, varscan2
- SCN9A | c.4928C>T p.A1643V (on ENST00000303354; = p.A1632V on NM_002977.3) | Missense Mutation (SNP) | VAF 39/97 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs879253994, CM085689, COSV100314603; called by muse, mutect2, varscan2
- SCN9A | c.2857G>T p.V953F (on ENST00000303354; = p.V942F on NM_002977.3) | Missense Mutation (SNP) | VAF 28/87 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs775257309, COSV100314606; called by muse, mutect2, varscan2
- SELENON | c.1187T>C p.L396P | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.564); catalogued as COSV100823608; called by muse, mutect2, varscan2
- SERPINB8 | c.1103G>A p.C368Y | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.934); catalogued as COSV99729461; called by muse, mutect2, varscan2
- SHANK1 | c.5792C>T p.S1931L | Missense Mutation (SNP) | VAF 11/68 reads (16%) | SIFT deleterious (0.05); PolyPhen benign (0.001); catalogued as COSV53241927, COSV99522289; called by muse, mutect2, varscan2
- SLC12A7 | c.2056del p.H686Tfs*11 | Frame Shift Del (DEL) | VAF 28/78 reads (36%) | catalogued as rs767964038; called by mutect2, pindel, varscan2
- SLC17A4 | c.721G>A p.A241T | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT tolerated (0.05); PolyPhen benign (0.152); catalogued as COSV100930704; called by muse, mutect2, varscan2
- SLC22A1 | c.1108G>A p.A370T | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.227); catalogued as rs755995720, COSV100267116; called by muse, mutect2, varscan2
- SLC44A4 | c.319G>A p.G107S | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as rs145124803; called by muse, mutect2, varscan2
- SLC6A3 | c.1639dup p.H547Pfs*56 | Frame Shift Ins (INS) | VAF 6/21 reads (29%) | catalogued as rs749320240; called by mutect2, varscan2
- SMC6 | c.1228del p.I410Yfs*4 | Frame Shift Del (DEL) | VAF 19/51 reads (37%) | catalogued as rs760667210; called by mutect2, varscan2
- SMG7 | c.2545del p.M849* | Frame Shift Del (DEL) | VAF 9/52 reads (17%) | catalogued as rs749889899; called by mutect2, varscan2
- SNAPC2 | c.799del p.Q267Sfs*38 | Frame Shift Del (DEL) | VAF 7/18 reads (39%) | catalogued as rs769564442; called by mutect2, pindel, varscan2
- SNTA1 | c.1105C>T p.R369C | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs369968387; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SNX30 | c.773C>T p.T258I | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.767); catalogued as COSV100953988; called by muse, mutect2
- SOAT2 | c.830G>A p.C277Y | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100037706; called by mutect2, varscan2
- SOGA1 | c.2729T>G p.L910R | Missense Mutation (SNP) | VAF 3/33 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99415993; called by muse, mutect2
- SPATA31A3 | c.2255G>A p.R752Q | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT tolerated (0.72); PolyPhen benign (0.001); catalogued as rs1337481865; called by mutect2, varscan2
- SPEG | c.3918dup p.R1307Qfs*45 | Frame Shift Ins (INS) | VAF 14/61 reads (23%) | catalogued as rs771765677; called by mutect2, varscan2
- SPINK8 | c.80C>A p.P27H | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV71285851; called by muse, mutect2, varscan2
- SPOCD1 | c.3282del p.R1095Gfs*32 | Frame Shift Del (DEL) | VAF 20/53 reads (38%) | catalogued as rs1455579753; called by mutect2, pindel, varscan2
- SPOCD1 | c.569del p.P190Lfs*5 | Frame Shift Del (DEL) | VAF 22/62 reads (35%) | catalogued as rs1419755215; called by mutect2, pindel, varscan2
- SPOCK2 | c.34C>T p.P12S | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0.001); catalogued as COSV100436515; called by muse, mutect2
- SPSB3 | c.475G>A p.V159I | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.999); catalogued as rs372168834; called by muse, mutect2, varscan2
- SPTBN1 | c.3658G>A p.A1220T | Missense Mutation (SNP) | VAF 19/43 reads (44%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.49); catalogued as COSV100443633; called by muse, mutect2, varscan2
- SPTBN1 | c.4679C>A p.A1560D | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as COSV100443636; called by muse, mutect2, varscan2
- SRD5A2 | c.163C>A p.L55M | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.955); catalogued as COSV99252693; called by muse, mutect2
- SRPRA | c.1276G>A p.V426I | Missense Mutation (SNP) | VAF 13/24 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs1170905226, COSV99703198; called by muse, mutect2, varscan2
- SRRM4 | c.434G>T p.R145L | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.062); catalogued as COSV99939707; called by muse, mutect2, varscan2
- SSC4D | c.57del p.W20Gfs*39 | Frame Shift Del (DEL) | VAF 8/13 reads (62%) | catalogued as COSV51882686; called by mutect2, varscan2
- SSTR3 | c.1082G>T p.S361I | Missense Mutation (SNP) | VAF 40/70 reads (57%) | SIFT tolerated (0.17); PolyPhen benign (0.01); catalogued as COSV100142943; called by muse, mutect2, varscan2
- STAB1 | c.5343G>A p.W1781* | Nonsense Mutation (SNP) | VAF 11/31 reads (35%) | catalogued as COSV100195590; called by muse, mutect2, varscan2
- STARD8 | c.1919T>A p.V640E | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV99367806; called by muse, mutect2, varscan2
- STKLD1 | c.1766_1768del p.E589del | In Frame Del (DEL) | VAF 14/26 reads (54%) | catalogued as rs782141470; called by pindel, varscan2
- SUCLG1 | c.350T>C p.V117A | Missense Mutation (SNP) | VAF 10/20 reads (50%) | SIFT tolerated (0.17); PolyPhen benign (0.357); catalogued as COSV101205467, COSV67265992; called by muse, mutect2, varscan2
- SVIL | c.4089C>A p.N1363K (on ENST00000355867 / NM_021738.3; = p.N937K on NM_003174.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 25/94 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV63443844; called by muse, mutect2, varscan2
- SYMPK | c.187A>G p.I63V | Missense Mutation (SNP) | VAF 33/87 reads (38%) | SIFT tolerated (0.33); PolyPhen benign (0.033); catalogued as COSV99842265; called by muse, mutect2, varscan2
- TAB3 | c.16C>T p.P6S | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT tolerated (1); PolyPhen possibly damaging (0.46); catalogued as COSV99916957; called by mutect2, varscan2
- TAS2R42 | c.215C>T p.A72V | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT tolerated (0.5); PolyPhen benign (0.085); catalogued as COSV100516941; called by muse, mutect2, varscan2
- TBC1D8B | c.2099C>T p.A700V | Missense Mutation (SNP) | VAF 20/42 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99345215; called by muse, mutect2, varscan2
- TBR1 | c.281G>A p.R94H | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV101271572; called by muse, mutect2, varscan2
- TCP11L1 | c.1327+2T>C p.X443_splice | Splice Site (SNP) | VAF 7/39 reads (18%) | catalogued as COSV100178454; called by muse, mutect2, varscan2
- TENT2 | c.1019A>G p.Y340C | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99706812; called by muse, mutect2, varscan2
- TENT5D | c.1147C>T p.R383C | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.003); catalogued as rs199636557, COSV57638732; called by muse, mutect2, varscan2
- TERT | c.1864C>T p.R622C | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as CM1515385, COSV99721495; called by muse, mutect2, varscan2
- TG | c.8297A>G p.Y2766C | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); catalogued as COSV99603922; called by muse, mutect2, varscan2
- TGFB1I1 | c.1262G>A p.G421D (on ENST00000394863 / NM_001042454.3; = p.G404D on NM_015927.4) | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.678); catalogued as COSV100691283; called by muse, mutect2, varscan2
- THOC2 | c.1098T>A p.D366E | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT tolerated (0.12); PolyPhen benign (0.074); catalogued as COSV99834463; called by muse, mutect2
- THRAP3 | c.2178del p.K726Nfs*170 | Frame Shift Del (DEL) | VAF 22/52 reads (42%) | catalogued as COSV63569106; called by mutect2, pindel, varscan2
- THRB | c.346G>A p.G116R | Missense Mutation (SNP) | VAF 11/69 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1467459460; called by muse, mutect2, varscan2
- TICAM1 | c.707C>T p.A236V | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT tolerated (0.1); PolyPhen benign (0.142); catalogued as COSV99941341; called by muse, mutect2, varscan2
- TMCC3 | c.865G>A p.V289M | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT tolerated (0.29); PolyPhen benign (0.007); catalogued as rs142686550; called by muse, mutect2, varscan2
- TMEM106A | c.755C>A p.S252Y | Missense Mutation (SNP) | VAF 19/43 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.89); catalogued as COSV100526253; called by muse, mutect2, varscan2
- TMEM11 | c.217C>A p.R73S | Missense Mutation (SNP) | VAF 33/65 reads (51%) | SIFT deleterious (0); PolyPhen benign (0.261); catalogued as COSV100471879, COSV100471976; called by muse, mutect2, varscan2
- TMEM132B | c.2719G>A p.V907I | Missense Mutation (SNP) | VAF 34/92 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs751942292, COSV54747583; called by muse, mutect2
- TMEM200C | c.512T>C p.L171P | Missense Mutation (SNP) | VAF 3/30 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101274879; called by muse, mutect2
- TMEM63A | c.1469A>G p.E490G | Missense Mutation (SNP) | VAF 10/91 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as rs1321709889, COSV100834460; called by muse, mutect2, varscan2
- TMPRSS15 | c.2054C>T p.T685M | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT tolerated (0.45); PolyPhen benign (0.007); catalogued as rs750285967, COSV53034292, COSV53035773; called by muse, mutect2, varscan2
- TNS1 | c.52G>A p.V18I | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs147171878; called by muse, mutect2, varscan2
- TOGARAM1 | c.3713C>G p.T1238S | Missense Mutation (SNP) | VAF 8/67 reads (12%) | SIFT tolerated (0.24); PolyPhen benign (0.175); catalogued as COSV100818311; called by muse, mutect2, varscan2
- TOMM70 | c.1189G>A p.D397N | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.656); catalogued as rs762230068, COSV99424582; called by muse, mutect2, varscan2
- TONSL | c.3346C>T p.R1116C | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.031); catalogued as rs782353998, COSV68047796; called by muse, mutect2, varscan2
- TOP2A | c.14C>T p.P5L | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.676); catalogued as COSV70733729; called by muse, mutect2, varscan2
- TOP3B | c.2239G>A p.A747T | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT tolerated (0.4); PolyPhen benign (0.007); catalogued as COSV99601776; called by mutect2, varscan2
- TP53BP2 | c.594dup p.V199Sfs*5 (on ENST00000343537 / NM_001031685.3; = p.V70Sfs*5 on NM_005426.2) | Frame Shift Ins (INS) | VAF 27/93 reads (29%) | catalogued as rs1367948348; called by mutect2, varscan2
- TP63 | c.533A>G p.D178G | Missense Mutation (SNP) | VAF 17/34 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV99289436; called by muse, mutect2, varscan2
- TRABD2A | c.1274G>A p.R425Q (on ENST00000409520 / NM_001277053.2; = p.R376Q on NM_001080824.3) | Missense Mutation (SNP) | VAF 22/46 reads (48%) | SIFT tolerated (0.15); PolyPhen benign (0.001); catalogued as rs544748549, COSV52851850; called by muse, mutect2, varscan2
- TRAF5 | c.1364G>T p.R455M | Missense Mutation (SNP) | VAF 27/88 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.077); catalogued as COSV99807703; called by muse, mutect2, varscan2
- TREH | c.1411dup p.L471Pfs*34 | Frame Shift Ins (INS) | VAF 24/65 reads (37%) | catalogued as rs782422052; called by mutect2, pindel, varscan2
- TRIM68 | c.1249C>T p.P417S | Missense Mutation (SNP) | VAF 3/32 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs1407807049, COSV56169954; called by muse, mutect2
- TRIM68 | c.805A>G p.R269G | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.022); catalogued as COSV100331866; called by muse, mutect2, varscan2
- TRIOBP | c.4436del p.G1479Afs*28 | Frame Shift Del (DEL) | VAF 10/68 reads (15%) | catalogued as rs756145453; called by mutect2, pindel, varscan2
- TRMT5 | c.205_208del p.E69Lfs*13 | Frame Shift Del (DEL) | VAF 10/27 reads (37%) | catalogued as rs770316501; called by mutect2, pindel, varscan2
- TRPC3 | c.331G>A p.A111T (on ENST00000379645 / NM_001366479.2; = p.A38T on NM_003305.2) | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as rs200365791, COSV99313685; called by muse, mutect2, varscan2
- TRPM2 | c.3541G>A p.E1181K | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100309486; called by muse, mutect2, varscan2
- TRPM6 | c.2771G>A p.G924D | Missense Mutation (SNP) | VAF 15/32 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100667131; called by muse, mutect2, varscan2
- TRRAP | c.9563G>A p.R3188Q (on ENST00000359863 / NM_001244580.1; = p.R3159Q on NM_003496.3) | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.207); catalogued as rs775078845, COSV100723226; called by muse, mutect2, varscan2
- TSNAXIP1 | c.1187A>G p.D396G | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.42); catalogued as COSV99535425; called by muse, mutect2, varscan2
- TUBB4A | c.646A>G p.K216E | Missense Mutation (SNP) | VAF 34/84 reads (40%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.785); catalogued as COSV51173039; called by muse, mutect2, varscan2
- TVP23A | c.420del p.F140Lfs*7 | Frame Shift Del (DEL) | VAF 8/28 reads (29%) | catalogued as rs760251146; called by mutect2, varscan2
- UBE3A | c.892A>G p.S298G | Missense Mutation (SNP) | VAF 18/40 reads (45%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.783); catalogued as COSV99217673; called by muse, mutect2, varscan2
- UGT1A1 | c.633G>T p.K211N | Missense Mutation (SNP) | VAF 4/78 reads (5%) | SIFT tolerated (0.23); PolyPhen benign (0.111); catalogued as COSV100531338; called by muse, mutect2
- UNC45B | c.2564G>T p.R855L | Missense Mutation (SNP) | VAF 15/30 reads (50%) | SIFT tolerated (0.66); PolyPhen benign (0.283); catalogued as COSV99269411; called by muse, mutect2, varscan2
- UNC5CL | c.1183G>A p.A395T | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as COSV99771061; called by muse, mutect2, varscan2
- UPF3A | c.798del p.E267Rfs*13 | Frame Shift Del (DEL) | VAF 14/36 reads (39%) | catalogued as rs767420916; called by mutect2, varscan2
- UPRT | c.672A>T p.K224N | Missense Mutation (SNP) | VAF 17/33 reads (52%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV100975856; called by muse, mutect2, varscan2
- URGCP | c.377A>G p.N126S (on ENST00000453200 / NM_001077663.3; = p.N117S on NM_017920.4) | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT tolerated (0.12); PolyPhen benign (0.005); catalogued as rs1002832860, COSV56249846; called by muse, mutect2, varscan2
- USP10 | c.2290C>T p.R764C | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.344); catalogued as rs1265922762, COSV54748721; called by muse, mutect2, varscan2
- USP35 | c.1059del p.M354Wfs*119 | Frame Shift Del (DEL) | VAF 20/53 reads (38%) | catalogued as rs761345427; called by mutect2, pindel, varscan2
- UVSSA | c.832G>T p.G278C | Missense Mutation (SNP) | VAF 3/46 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.258); catalogued as COSV101104403, COSV66230306; called by muse, mutect2
- VCPIP1 | c.105dup p.L36Afs*51 | Frame Shift Ins (INS) | VAF 6/18 reads (33%) | catalogued as rs755078234; called by mutect2, varscan2
- VIL1 | c.2049G>T p.K683N | Missense Mutation (SNP) | VAF 17/37 reads (46%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.491); catalogued as COSV99945958; called by muse, mutect2, varscan2
- VWF | c.7130dup p.H2378Afs*13 | Frame Shift Ins (INS) | VAF 9/18 reads (50%) | catalogued as rs267607359; ClinVar: not provided; called by mutect2, varscan2
- WDR27 | c.2080G>A p.A694T | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.744); catalogued as COSV100360017; called by muse, mutect2, varscan2
- WDR7 | c.2908_2910del p.S970del | In Frame Del (DEL) | VAF 14/48 reads (29%) | catalogued as rs199884319; called by mutect2, pindel, varscan2
- WDTC1 | c.1576T>G p.Y526D (on ENST00000319394 / NM_001276252.2; = p.Y525D on NM_015023.5) | Missense Mutation (SNP) | VAF 28/64 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV100089672; called by muse, mutect2, varscan2
- WFS1 | c.133G>A p.G45R | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.007); catalogued as rs1014892217, COSV99901705; called by muse, mutect2, varscan2
- WIPF2 | c.923G>A p.S308N | Missense Mutation (SNP) | VAF 10/17 reads (59%) | SIFT tolerated (0.06); PolyPhen benign (0.107); catalogued as COSV100064036; called by muse, mutect2, varscan2
- WNT9A | c.868G>A p.V290M | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.292); catalogued as rs759994026, COSV99688204; called by muse, mutect2, varscan2
- WWC2 | c.3191G>T p.R1064L | Missense Mutation (SNP) | VAF 20/31 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101331125; called by muse, mutect2, varscan2
- XPO7 | c.2855G>A p.R952H | Missense Mutation (SNP) | VAF 18/43 reads (42%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.775); catalogued as rs368230317; called by muse, mutect2, varscan2
- XRRA1 | c.2194C>A p.L732M | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100213635; called by muse, mutect2, varscan2
- YIF1A | c.391dup p.R131Pfs*8 | Frame Shift Ins (INS) | VAF 8/26 reads (31%) | catalogued as rs761507279; called by mutect2, varscan2
- YIPF6 | c.44C>T p.S15L | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.001); catalogued as rs372703496, COSV101006290; called by muse, mutect2, varscan2
- ZBTB34 | c.955C>T p.R319C | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.295); catalogued as rs200977337, COSV59860164; called by muse, mutect2, varscan2
- ZFHX4 | c.1230dup p.L411Afs*3 | Frame Shift Ins (INS) | VAF 7/20 reads (35%) | catalogued as rs761578656; called by mutect2, varscan2
- ZMYM6 | c.1690C>T p.R564* | Nonsense Mutation (SNP) | VAF 12/27 reads (44%) | catalogued as rs748753112, COSV64121067; called by muse, mutect2, varscan2
- ZNF106 | c.4349G>A p.S1450N | Missense Mutation (SNP) | VAF 15/109 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.963); catalogued as COSV99783340; called by muse, mutect2, varscan2
- ZNF131 | c.518C>T p.A173V | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.054); catalogued as COSV61001891; called by muse, mutect2, varscan2
- ZNF175 | c.1360C>T p.Q454* | Nonsense Mutation (SNP) | VAF 6/29 reads (21%) | catalogued as COSV99219874; called by muse, mutect2, varscan2
- ZNF214 | c.17A>G p.E6G | Missense Mutation (SNP) | VAF 15/30 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.696); catalogued as COSV99547717; called by muse, mutect2, varscan2
- ZNF318 | c.4579C>T p.R1527* | Nonsense Mutation (SNP) | VAF 25/53 reads (47%) | catalogued as rs765911486, COSV100546592; called by muse, mutect2, varscan2
- ZNF446 | c.998C>T p.T333M | Missense Mutation (SNP) | VAF 7/56 reads (13%) | SIFT tolerated (0.24); PolyPhen benign (0.006); catalogued as rs375255776; called by muse, mutect2, varscan2
- ZNF462 | c.4873A>G p.T1625A | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99473717; called by muse, mutect2, varscan2
- ZNF548 | c.997G>A p.G333R | Missense Mutation (SNP) | VAF 16/37 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.241); catalogued as rs377304568; called by muse, mutect2, varscan2
- ZNF585B | c.1835G>T p.G612V | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100459714; called by muse, mutect2, varscan2
- ZNF609 | c.847C>T p.R283C | Missense Mutation (SNP) | VAF 24/73 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs777951987, COSV58581926; called by muse, mutect2, varscan2
- ZNF71 | c.371G>A p.C124Y | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as COSV100045399; called by muse, mutect2, varscan2
- ZNF772 | c.8C>T p.A3V | Missense Mutation (SNP) | VAF 22/48 reads (46%) | SIFT tolerated, low confidence (0.62); PolyPhen benign (0.028); catalogued as COSV100582959; called by mutect2, varscan2
- ZNF862 | c.811del p.D271Mfs*9 | Frame Shift Del (DEL) | VAF 16/47 reads (34%) | catalogued as rs769847259; called by mutect2, pindel, varscan2
- ZSCAN10 | c.760G>A p.G254R (on ENST00000252463; = p.G309R on NM_032805.3) | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.474); catalogued as rs959281745, COSV52971410; called by muse, mutect2, varscan2
- ZSCAN2 | c.1247A>G p.K416R | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.071); catalogued as rs960063939, COSV100306994; called by muse, mutect2
- ZSCAN2 | c.1607G>A p.G536D | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.628); catalogued as rs866817741, COSV100306997; called by muse, mutect2, varscan2
- ACAP2 | c.1456del p.M486Wfs*3 | Frame Shift Del (DEL) | VAF 11/36 reads (31%) | called by mutect2, pindel, varscan2
- ACVR2B | c.389del p.P130Rfs*58 | Frame Shift Del (DEL) | VAF 9/27 reads (33%) | called by mutect2, pindel, varscan2
- ADGRL1 | c.3885dup p.S1296Efs*12 (on ENST00000340736 / NM_001008701.3; = p.S1291Efs*12 on NM_014921.5) | Frame Shift Ins (INS) | VAF 17/45 reads (38%) | called by mutect2, pindel, varscan2
- ADORA1 | c.364del p.R122Gfs*7 | Frame Shift Del (DEL) | VAF 18/75 reads (24%) | called by mutect2, pindel, varscan2
- ANGPTL2 | c.761del p.P254Lfs*41 | Frame Shift Del (DEL) | VAF 17/46 reads (37%) | called by mutect2, pindel, varscan2
- ARID1A | c.6420del p.F2141Sfs*59 | Frame Shift Del (DEL) | VAF 16/46 reads (35%) | called by mutect2, pindel, varscan2
- ARR3 | c.682dup p.I228Nfs*6 | Frame Shift Ins (INS) | VAF 8/29 reads (28%) | called by mutect2, varscan2
- ASIC2 | c.897del p.P300Lfs*48 | Frame Shift Del (DEL) | VAF 8/86 reads (9%) | called by mutect2, pindel
- ATP13A2 | c.2308del p.Q770Rfs*4 | Frame Shift Del (DEL) | VAF 22/52 reads (42%) | called by mutect2, pindel, varscan2
- ATP8B1 | c.3314del p.G1105Efs*36 | Frame Shift Del (DEL) | VAF 7/20 reads (35%) | called by mutect2, varscan2
- ATXN7 | c.2340del p.T781Pfs*11 | Frame Shift Del (DEL) | VAF 7/22 reads (32%) | called by mutect2, pindel, varscan2
- BCHE | c.147del p.F49Lfs*5 | Frame Shift Del (DEL) | VAF 30/71 reads (42%) | called by mutect2, pindel, varscan2
- BRF1 | c.876del p.S293Rfs*11 | Frame Shift Del (DEL) | VAF 6/18 reads (33%) | called by mutect2, pindel, varscan2
- CCND1 | c.871_879del p.R291_V293del | In Frame Del (DEL) | VAF 4/16 reads (25%) | called by mutect2, varscan2
- CCT6B | c.1506del p.K502Nfs*9 | Frame Shift Del (DEL) | VAF 14/60 reads (23%) | called by pindel, varscan2
- CD93 | c.943del p.A315Pfs*273 | Frame Shift Del (DEL) | VAF 23/67 reads (34%) | called by mutect2, pindel, varscan2
- CDC42BPG | c.4627del p.L1543Yfs*14 | Frame Shift Del (DEL) | VAF 14/48 reads (29%) | called by mutect2, pindel, varscan2
- CDK18 | c.1333_1336dup p.A446Vfs*22 (on ENST00000506784 / NM_212503.3; = p.A416Vfs*22 on NM_002596.4) | Frame Shift Ins (INS) | VAF 7/27 reads (26%) | called by mutect2, pindel, varscan2
- CFTR | c.49_50del p.F17Qfs*27 | Frame Shift Del (DEL) | VAF 17/53 reads (32%) | called by mutect2, pindel, varscan2
- CHD3 | c.1618del p.R540Vfs*16 | Frame Shift Del (DEL) | VAF 14/40 reads (35%) | called by mutect2, pindel, varscan2
- CLTA | c.469dup p.T157Nfs*10 (on ENST00000242285 / NM_007096.4; = p.T157Nfs*15 on NM_001833.4 and 2 other RefSeq transcripts) | Frame Shift Ins (INS) | VAF 13/51 reads (25%) | called by mutect2, pindel, varscan2
- CSN1S1 | c.536del p.N179Ifs*16 | Frame Shift Del (DEL) | VAF 21/76 reads (28%) | called by mutect2, pindel, varscan2
- CTCF | c.610del p.T204Qfs*18 | Frame Shift Del (DEL) | VAF 12/31 reads (39%) | called by mutect2, pindel, varscan2
- DDR1 | c.1448del p.P483Rfs*170 (on ENST00000324771; = p.P483Rfs*133 on NM_001954.4) | Frame Shift Del (DEL) | VAF 4/47 reads (9%) | called by mutect2, pindel
- DHX36 | c.134del p.G45Vfs*13 | Frame Shift Del (DEL) | VAF 14/34 reads (41%) | called by mutect2, pindel, varscan2
- DLGAP1 | c.1821dup p.A608Rfs*14 | Frame Shift Ins (INS) | VAF 24/82 reads (29%) | called by mutect2, pindel, varscan2
- DLGAP5 | c.2312dup p.N771Kfs*7 | Frame Shift Ins (INS) | VAF 18/43 reads (42%) | called by mutect2, varscan2
- DOCK4 | c.2127del p.F709Lfs*4 | Frame Shift Del (DEL) | VAF 10/25 reads (40%) | called by mutect2, pindel, varscan2
- EVX2 | c.245del p.T82Rfs*33 | Frame Shift Del (DEL) | VAF 17/59 reads (29%) | called by mutect2, pindel, varscan2
- FAM20B | c.220del p.R74Gfs*35 | Frame Shift Del (DEL) | VAF 8/28 reads (29%) | called by mutect2, pindel, varscan2
- FRY | c.7182dup p.E2395Rfs*34 | Frame Shift Ins (INS) | VAF 11/36 reads (31%) | called by mutect2, pindel, varscan2
- GOLGB1 | c.2444del p.L815Yfs*18 | Frame Shift Del (DEL) | VAF 19/40 reads (48%) | called by mutect2, varscan2
- GPSM3 | c.50del p.P17Lfs*77 | Frame Shift Del (DEL) | VAF 19/63 reads (30%) | called by mutect2, pindel, varscan2
- HCFC2 | c.1014dup p.A339Sfs*4 | Frame Shift Ins (INS) | VAF 12/28 reads (43%) | called by mutect2, pindel, varscan2
- HEATR5A | c.3775del p.R1259Efs*15 | Frame Shift Del (DEL) | VAF 34/95 reads (36%) | called by mutect2, pindel, varscan2
- HEATR5A | c.1000dup p.S334Ffs*13 | Frame Shift Ins (INS) | VAF 10/26 reads (38%) | called by mutect2, varscan2
- HSPA8 | c.199_202del p.V67Lfs*6 | Frame Shift Del (DEL) | VAF 14/31 reads (45%) | called by mutect2, pindel*, varscan2
- HSPD1 | c.368_369del p.I123Sfs*9 | Frame Shift Del (DEL) | VAF 18/61 reads (30%) | called by pindel, varscan2
- ICAM5 | c.923del p.G308Afs*10 | Frame Shift Del (DEL) | VAF 15/43 reads (35%) | called by mutect2, pindel, varscan2
- IGF2R | c.1544del p.F515Sfs*42 | Frame Shift Del (DEL) | VAF 5/39 reads (13%) | called by mutect2, pindel, varscan2
- IGKV3D-15 | c.19C>A p.L7I | Missense Mutation (SNP) | VAF 37/117 reads (32%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.905); called by muse, mutect2, varscan2
- INO80D | c.1638del p.K546Nfs*49 | Frame Shift Del (DEL) | VAF 23/72 reads (32%) | called by mutect2, pindel, varscan2
- INTS2 | c.485del p.F162Sfs*33 | Frame Shift Del (DEL) | VAF 8/48 reads (17%) | called by mutect2, varscan2
- IRAK4 | c.282del p.F94Lfs*25 | Frame Shift Del (DEL) | VAF 14/42 reads (33%) | called by mutect2, pindel, varscan2
- IREB2 | c.15del p.A6Qfs*12 | Frame Shift Del (DEL) | VAF 5/58 reads (9%) | called by mutect2, pindel, varscan2
- JAK1 | c.1035del p.K345Nfs*32 | Frame Shift Del (DEL) | VAF 8/35 reads (23%) | called by mutect2, pindel, varscan2
- KANSL1 | c.74del p.P25Hfs*37 | Frame Shift Del (DEL) | VAF 7/44 reads (16%) | called by mutect2, pindel, varscan2
- KDM4A | c.1813del p.R605Afs*20 | Frame Shift Del (DEL) | VAF 10/37 reads (27%) | called by mutect2, pindel, varscan2
- KMT2C | c.5152del p.R1718Gfs*23 | Frame Shift Del (DEL) | VAF 35/116 reads (30%) | called by mutect2, pindel, varscan2
- LONP1 | c.1574del p.P525Lfs*16 | Frame Shift Del (DEL) | VAF 11/43 reads (26%) | called by mutect2, pindel, varscan2
- MACROD2 | c.1236del p.A413Lfs*19 (on ENST00000642719; = p.A385Lfs*19 on NM_080676.6 and 2 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 7/20 reads (35%) | called by mutect2, pindel, varscan2
- MAP1A | c.5993del p.P1998Hfs*72 | Frame Shift Del (DEL) | VAF 20/47 reads (43%) | called by mutect2, pindel, varscan2
- MAP3K12 | c.1605del p.S536Hfs*45 | Frame Shift Del (DEL) | VAF 16/34 reads (47%) | called by mutect2, pindel, varscan2
- MBOAT7 | c.145dup p.H49Pfs*70 | Frame Shift Ins (INS) | VAF 12/59 reads (20%) | called by mutect2, pindel, varscan2
- MEGF8 | c.1593del p.Y532Tfs*9 | Frame Shift Del (DEL) | VAF 19/109 reads (17%) | called by mutect2, varscan2
- MGA | c.6710del p.L2237* (on ENST00000219905 / NM_001164273.1; = p.L2028* on NM_001080541.2) | Frame Shift Del (DEL) | VAF 6/25 reads (24%) | called by mutect2, pindel, varscan2
- MID1IP1 | c.206del p.P69Qfs*174 | Frame Shift Del (DEL) | VAF 7/48 reads (15%) | called by mutect2, pindel, varscan2
- MTSS2 | c.1677del p.G560Afs*34 | Frame Shift Del (DEL) | VAF 10/22 reads (45%) | called by mutect2, pindel, varscan2
- MYO15A | c.7534del p.V2512Cfs*31 | Frame Shift Del (DEL) | VAF 5/50 reads (10%) | called by mutect2, pindel, varscan2
- NDST1 | c.559del p.L187Cfs*9 | Frame Shift Del (DEL) | VAF 9/38 reads (24%) | called by mutect2, pindel, varscan2
- NEMF | c.1367del p.N456Ifs*6 | Frame Shift Del (DEL) | VAF 9/28 reads (32%) | called by mutect2, pindel, varscan2
- NRXN1 | c.852del p.T285Rfs*24 | Frame Shift Del (DEL) | VAF 11/31 reads (35%) | called by mutect2, pindel, varscan2
- NSD1 | c.4591del p.M1531Cfs*43 | Frame Shift Del (DEL) | VAF 18/62 reads (29%) | called by mutect2, pindel, varscan2
- NUFIP1 | c.526dup p.C176Lfs*2 | Frame Shift Ins (INS) | VAF 11/34 reads (32%) | called by mutect2, varscan2
- OIT3 | c.1436_1437del p.P479Rfs*105 | Frame Shift Del (DEL) | VAF 10/29 reads (34%) | called by pindel, varscan2
- PADI4 | c.1566del p.K522Nfs*5 | Frame Shift Del (DEL) | VAF 7/16 reads (44%) | called by mutect2, varscan2
- PCDHA12 | c.558del p.D187Ifs*8 | Frame Shift Del (DEL) | VAF 6/18 reads (33%) | called by mutect2, pindel, varscan2
- PGR | c.2166_2167del p.R724Afs*10 | Frame Shift Del (DEL) | VAF 20/64 reads (31%) | called by mutect2, pindel, varscan2
- PHF14 | c.545_546del p.K182Mfs*20 | Frame Shift Del (DEL) | VAF 7/24 reads (29%) | called by mutect2, pindel, varscan2
- PIK3R1 | c.1585_1587del p.D529del (on ENST00000521381 / NM_181523.3; = p.D259del on NM_181504.4) | In Frame Del (DEL) | VAF 9/40 reads (23%) | called by pindel, varscan2
- PLEKHG1 | c.726del p.S243Pfs*4 | Frame Shift Del (DEL) | VAF 14/42 reads (33%) | called by mutect2, pindel, varscan2
- PROX1 | c.1780del p.Y594Ifs*10 | Frame Shift Del (DEL) | VAF 15/63 reads (24%) | called by mutect2, pindel, varscan2
- PTEN | c.867dup p.V290Sfs*8 | Frame Shift Ins (INS) | VAF 16/37 reads (43%) | called by mutect2, pindel, varscan2
- PTPN5 | c.33_34dup p.N12Rfs*28 | Frame Shift Ins (INS) | VAF 9/36 reads (25%) | called by mutect2, varscan2
- RAB39B | c.535dup p.E179Gfs*49 | Frame Shift Ins (INS) | VAF 14/50 reads (28%) | called by mutect2, pindel, varscan2
- RORA | c.856del p.E286Kfs*6 (on ENST00000335670 / NM_134261.3; = p.E311Kfs*6 on NM_002943.3) | Frame Shift Del (DEL) | VAF 29/77 reads (38%) | called by mutect2, pindel, varscan2
- RPTN | c.2197dup p.T733Nfs*3 | Frame Shift Ins (INS) | VAF 64/196 reads (33%) | called by mutect2, pindel, varscan2
- RTL5 | c.1588del p.Q530Nfs*2 | Frame Shift Del (DEL) | VAF 22/54 reads (41%) | called by mutect2, pindel, varscan2
- SCAF11 | c.2009del p.N670Ifs*4 | Frame Shift Del (DEL) | VAF 6/30 reads (20%) | called by mutect2, pindel, varscan2
- SHROOM2 | c.953del p.P318Lfs*143 | Frame Shift Del (DEL) | VAF 14/40 reads (35%) | called by mutect2, pindel, varscan2
- SKIV2L | c.32del p.P11Lfs*23 | Frame Shift Del (DEL) | VAF 8/27 reads (30%) | called by mutect2, pindel, varscan2
- SUPT16H | c.2956_2957del p.S986Wfs*6 | Frame Shift Del (DEL) | VAF 8/34 reads (24%) | called by pindel, varscan2
- TACR3 | c.41dup p.G15Wfs*24 | Frame Shift Ins (INS) | VAF 6/26 reads (23%) | called by mutect2, pindel, varscan2
- TAF15 | c.1589del p.G530Afs*116 (on ENST00000605844 / NM_139215.3; = p.G527Afs*116 on NM_003487.4) | Frame Shift Del (DEL) | VAF 17/59 reads (29%) | called by mutect2, pindel, varscan2
- TCHH | c.2423_2425del p.Q808del | In Frame Del (DEL) | VAF 8/27 reads (30%) | called by pindel, varscan2
- TET1 | c.3171del p.K1057Nfs*25 | Frame Shift Del (DEL) | VAF 12/36 reads (33%) | called by mutect2, pindel, varscan2
- TFDP2 | c.606del p.E203Kfs*20 (on ENST00000489671 / NM_001178139.2; = p.E143Kfs*20 on NM_006286.5) | Frame Shift Del (DEL) | VAF 7/41 reads (17%) | called by mutect2, varscan2
- TFE3 | c.1445del p.G482Dfs*44 | Frame Shift Del (DEL) | VAF 9/50 reads (18%) | called by mutect2, varscan2
- TLE1 | c.1834_1849del p.F612Tfs*70 | Frame Shift Del (DEL) | VAF 16/33 reads (48%) | called by mutect2, pindel, varscan2
- TNRC18 | c.6317del p.G2106Vfs*3 | Frame Shift Del (DEL) | VAF 51/188 reads (27%) | called by mutect2, pindel, varscan2
- TRPM8 | c.710del p.L237* | Frame Shift Del (DEL) | VAF 13/36 reads (36%) | called by mutect2, pindel, varscan2
- TTC30A | c.434del p.G145Efs*64 | Frame Shift Del (DEL) | VAF 34/88 reads (39%) | called by mutect2, pindel, varscan2
- TXNDC11 | c.1982-3del | Splice Region (DEL) | VAF 7/28 reads (25%) | called by mutect2, pindel, varscan2
- UPF3B | c.491del p.L164Wfs*11 | Frame Shift Del (DEL) | VAF 13/44 reads (30%) | called by mutect2, pindel, varscan2
- YLPM1 | c.440del p.P147Lfs*72 | Frame Shift Del (DEL) | VAF 13/37 reads (35%) | called by mutect2, pindel, varscan2
- ZNF319 | c.1372del p.L458Cfs*95 | Frame Shift Del (DEL) | VAF 7/22 reads (32%) | called by mutect2, pindel, varscan2
- AADACL4 | c.48C>T p.F16= | Silent (SNP) | VAF 22/81 reads (27%) | catalogued as COSV66106305; called by muse, mutect2, varscan2
- AARS1 | c.258C>T p.D86= | Silent (SNP) | VAF 22/54 reads (41%) | catalogued as COSV99933882; called by muse, mutect2, varscan2
- ACAD9 | c.324G>A p.G108= | Silent (SNP) | VAF 17/40 reads (43%) | catalogued as COSV100459483; called by muse, mutect2, varscan2
- ACTN4 | c.2409C>T p.N803= | Silent (SNP) | VAF 18/41 reads (44%) | catalogued as rs767454781, COSV99400779; called by muse, mutect2, varscan2
- ADAM30 | c.789C>T p.R263= | Silent (SNP) | VAF 4/9 reads (44%) | catalogued as rs374434107; called by muse, varscan2
- ADAMTS1 | c.2151C>T p.C717= | Silent (SNP) | VAF 22/55 reads (40%) | catalogued as rs7278894; called by muse, mutect2, varscan2
- ADAMTS13 | c.1164T>A p.S388= | Silent (SNP) | VAF 22/50 reads (44%) | catalogued as COSV100747254; called by muse, mutect2, varscan2
- ANKRD50 | c.3669G>A p.L1223= | Silent (SNP) | VAF 10/29 reads (34%) | catalogued as COSV101539070; called by muse, mutect2, varscan2
- ARHGAP17 | c.2160G>A p.T720= (on ENST00000289968 / NM_001006634.3; = p.T642= on NM_018054.6) | Silent (SNP) | VAF 20/48 reads (42%) | catalogued as rs772387053, COSV99254214; called by muse, mutect2, varscan2
- ARX | c.843A>G p.A281= | Silent (SNP) | VAF 4/13 reads (31%) | catalogued as COSV100984102; called by muse, mutect2, varscan2
- ASB10 | c.411G>A p.R137= (on ENST00000420175 / NM_001142459.2; = p.R122= on NM_080871.4) | Silent (SNP) | VAF 4/14 reads (29%) | catalogued as COSV104369810, COSV99319082; called by muse, mutect2
- ATN1 | c.3327C>T p.H1109= | Silent (SNP) | VAF 9/41 reads (22%) | catalogued as rs782316152, COSV99980868; called by muse, mutect2, varscan2
- ATP10A | c.4263C>T p.G1421= | Silent (SNP) | VAF 20/47 reads (43%) | catalogued as COSV100791649; called by muse, mutect2, varscan2
- ATP8B2 | c.2286C>T p.N762= (on ENST00000672630; = p.N729= on NM_001367934.1 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 14/40 reads (35%) | catalogued as rs768030196, COSV100528334; called by muse, mutect2, varscan2
- ATRIP | c.1842G>A p.A614= | Silent (SNP) | VAF 5/46 reads (11%) | catalogued as rs368208006; called by muse, mutect2, varscan2
- ATRX | c.837A>G p.A279= | Silent (SNP) | VAF 7/84 reads (8%) | catalogued as COSV100971660; called by muse, mutect2
- BAG5 | c.954T>C p.D318= | Silent (SNP) | VAF 10/38 reads (26%) | catalogued as COSV99915074; called by muse, mutect2, varscan2
- BANK1 | c.2277T>C p.Y759= | Silent (SNP) | VAF 29/74 reads (39%) | catalogued as COSV100537026; called by muse, mutect2, varscan2
- BRAT1 | c.1644G>A p.Q548= | Silent (SNP) | VAF 7/9 reads (78%) | catalogued as COSV100500755; called by muse, varscan2
- CAMK2G | c.282C>A p.T94= | Silent (SNP) | VAF 15/44 reads (34%) | catalogued as COSV59480564, COSV99990526; called by muse, mutect2, varscan2
- CARMIL2 | c.4266C>A p.P1422= | Silent (SNP) | VAF 22/54 reads (41%) | catalogued as COSV99538056; called by muse, mutect2, varscan2
- CDK5RAP2 | c.4269G>A p.L1423= | Silent (SNP) | VAF 12/32 reads (38%) | catalogued as COSV100575815; called by muse, mutect2, varscan2
- CLCN7 | c.1302G>A p.S434= | Silent (SNP) | VAF 8/27 reads (30%) | catalogued as rs140669487; called by muse, mutect2, varscan2
- CPXM2 | c.1599C>A p.P533= | Silent (SNP) | VAF 7/30 reads (23%) | catalogued as COSV99580932, COSV99583610; called by muse, mutect2, varscan2
- CTDP1 | c.2832C>T p.S944= | Silent (SNP) | VAF 7/32 reads (22%) | catalogued as rs371648109; called by mutect2, varscan2
- DCAF12L2 | c.645C>T p.G215= | Silent (SNP) | VAF 49/128 reads (38%) | catalogued as COSV100758933; called by muse, mutect2, varscan2
- DCAF8L1 | c.15G>A p.E5= | Silent (SNP) | VAF 19/46 reads (41%) | catalogued as COSV101491587; called by muse, mutect2, varscan2
- DCDC1 | c.2040A>G p.S680= | Silent (SNP) | VAF 19/43 reads (44%) | catalogued as COSV100664384; called by muse, mutect2, varscan2
- DDX11 | c.2262G>A p.R754= (on ENST00000545668 / NM_152438.2; = p.R704= on NM_004399.3) | Silent (SNP) | VAF 14/162 reads (9%) | catalogued as rs757678697, COSV99300489; called by muse, mutect2
- DHRS11 | c.699C>T p.A233= | Silent (SNP) | VAF 3/45 reads (7%) | catalogued as rs769814105; called by muse, mutect2
- DUOX1 | c.3828C>T p.S1276= | Silent (SNP) | VAF 14/26 reads (54%) | catalogued as rs1386195691, COSV58480043; called by muse, mutect2, varscan2
- DYNC1H1 | c.8490G>A p.L2830= | Silent (SNP) | VAF 37/76 reads (49%) | catalogued as COSV100795581; called by muse, mutect2, varscan2
- ESRP2 | c.484C>A p.R162= | Silent (SNP) | VAF 26/61 reads (43%) | catalogued as COSV99251583; called by muse, mutect2, varscan2
- FANCA | c.3666G>A p.P1222= | Silent (SNP) | VAF 5/17 reads (29%) | catalogued as rs780031277, COSV99235466; called by muse, mutect2, varscan2
- FBF1 | c.2415C>T p.I805= (on ENST00000586717; = p.I819= on NM_001319193.1) | Silent (SNP) | VAF 9/30 reads (30%) | catalogued as rs566017159, COSV100045717, COSV59863854; called by muse, mutect2, varscan2
- FIZ1 | c.1359C>T p.H453= | Silent (SNP) | VAF 8/18 reads (44%) | catalogued as rs1214476183, COSV99684786; called by muse, varscan2
- FNDC1 | c.807G>A p.R269= | Silent (SNP) | VAF 10/60 reads (17%) | catalogued as COSV51939838; called by muse, mutect2, varscan2
- FNDC3A | c.885T>C p.G295= (on ENST00000492622 / NM_001079673.2; = p.G239= on NM_014923.5) | Silent (SNP) | VAF 29/79 reads (37%) | catalogued as rs112927362, COSV101001381; called by muse, mutect2, varscan2
- FZD7 | c.1413C>T p.I471= | Silent (SNP) | VAF 8/53 reads (15%) | catalogued as COSV53808205; called by muse, mutect2, varscan2
- GAK | c.474C>T p.A158= | Silent (SNP) | VAF 23/62 reads (37%) | catalogued as rs140230555; called by muse, mutect2, varscan2
- GANC | c.387C>T p.D129= | Silent (SNP) | VAF 23/55 reads (42%) | catalogued as rs1158784437, COSV100531332; called by muse, mutect2, varscan2
- GATD1 | c.369C>T p.A123= | Silent (SNP) | VAF 28/71 reads (39%) | catalogued as rs200422394; called by muse, mutect2, varscan2
- GOT2 | c.519C>T p.G173= | Silent (SNP) | VAF 22/63 reads (35%) | catalogued as rs541543249, COSV99804099; called by muse, mutect2, varscan2
- GPRC6A | c.1647T>C p.P549= | Silent (SNP) | VAF 17/72 reads (24%) | catalogued as COSV100114906; called by muse, mutect2, varscan2
- GRIN2A | c.3708C>T p.C1236= | Silent (SNP) | VAF 28/66 reads (42%) | catalogued as rs780909404, COSV58023313, COSV58047100; called by muse, mutect2, varscan2
- HAPLN3 | c.933C>T p.C311= | Silent (SNP) | VAF 17/44 reads (39%) | catalogued as rs374662292; called by muse, mutect2, varscan2
- HUNK | c.651G>A p.S217= | Silent (SNP) | VAF 28/64 reads (44%) | catalogued as rs763429549, COSV54226669; called by muse, mutect2, varscan2
- IL20RA | c.1143T>C p.S381= | Silent (SNP) | VAF 13/29 reads (45%) | catalogued as COSV100360277; called by muse, mutect2, varscan2
- IQSEC1 | c.2691G>A p.S897= | Silent (SNP) | VAF 17/51 reads (33%) | catalogued as rs760777591, COSV99832551; called by muse, mutect2, varscan2
- ITGA4 | c.723A>G p.K241= | Silent (SNP) | VAF 28/71 reads (39%) | catalogued as rs755912850, COSV99276984; called by muse, mutect2, varscan2
- ITPR3 | c.2106G>A p.E702= | Silent (SNP) | VAF 8/29 reads (28%) | catalogued as COSV100967296; called by muse, mutect2, varscan2
- KLHL26 | c.1476G>A p.A492= | Silent (SNP) | VAF 13/35 reads (37%) | catalogued as COSV56318649; called by muse, mutect2, varscan2
- LAMA1 | c.6084C>T p.D2028= | Silent (SNP) | VAF 12/46 reads (26%) | catalogued as rs773172566, COSV101058047; called by muse, mutect2, varscan2
- LHX6 | c.165G>A p.P55= (on ENST00000373755 / NM_001242334.2; = p.P84= on NM_014368.5) | Silent (SNP) | VAF 13/30 reads (43%) | catalogued as COSV100493650; called by muse, varscan2
- LLGL1 | c.2877G>A p.Q959= | Silent (SNP) | VAF 7/26 reads (27%) | catalogued as COSV100375770; called by muse, mutect2, varscan2
- MAP7D3 | c.1707T>C p.T569= | Silent (SNP) | VAF 12/42 reads (29%) | catalogued as COSV100286815; called by muse, mutect2, varscan2
- MED26 | c.1512C>G p.T504= | Silent (SNP) | VAF 13/34 reads (38%) | catalogued as COSV99660257; called by muse, mutect2, varscan2
- MESP2 | c.888G>A p.A296= | Silent (SNP) | VAF 28/64 reads (44%) | catalogued as rs374172103; called by muse, mutect2, varscan2
- MMP2 | c.975C>T p.R325= | Silent (SNP) | VAF 10/19 reads (53%) | catalogued as rs143619840; called by muse, mutect2, varscan2
- MTSS1 | c.423C>A p.S141= | Silent (SNP) | VAF 10/63 reads (16%) | catalogued as COSV61496337; called by muse, mutect2, varscan2
- MYBPC3 | c.3372C>T p.C1124= | Silent (SNP) | VAF 8/22 reads (36%) | catalogued as rs727504289, CM043550, COSV99921132; called by muse, mutect2, varscan2
- MYO18A | c.5169C>T p.I1723= | Silent (SNP) | VAF 9/37 reads (24%) | catalogued as rs765957174, COSV62874420; called by muse, mutect2, varscan2
- MYO1E | c.1080C>T p.H360= | Silent (SNP) | VAF 14/26 reads (54%) | catalogued as rs372487333; called by muse, mutect2, varscan2
- NAV1 | c.888C>T p.S296= | Silent (SNP) | VAF 25/92 reads (27%) | catalogued as rs1438637238, COSV55225035; called by muse, mutect2, varscan2
- NDUFB2 | c.186C>T p.S62= | Silent (SNP) | VAF 16/39 reads (41%) | catalogued as rs147835245; called by muse, mutect2, varscan2
- NELFB | c.501C>T p.H167= | Silent (SNP) | VAF 12/26 reads (46%) | catalogued as COSV100547093; called by muse, mutect2, varscan2
- NIBAN2 | c.1344C>T p.F448= | Silent (SNP) | VAF 23/48 reads (48%) | catalogued as rs756098208, COSV100964991; called by muse, mutect2, varscan2
- NKRF | c.504C>T p.A168= | Silent (SNP) | VAF 31/81 reads (38%) | catalogued as rs766020454, COSV100441963; called by muse, mutect2, varscan2
- NOTCH4 | c.3561C>T p.C1187= | Silent (SNP) | VAF 9/58 reads (16%) | catalogued as rs773915869, COSV66679197; called by muse, mutect2, varscan2
- NPHP4 | c.3423C>G p.L1141= | Silent (SNP) | VAF 6/25 reads (24%) | catalogued as rs1180640290, COSV100977159, COSV65395855; called by muse, mutect2, varscan2
- NUAK1 | c.1740C>T p.S580= | Silent (SNP) | VAF 5/24 reads (21%) | catalogued as rs540753037, COSV54608829; called by muse, mutect2, varscan2
- NUB1 | c.261A>T p.I87= | Silent (SNP) | VAF 10/24 reads (42%) | catalogued as COSV100879398; called by muse, mutect2
- NUBP2 | c.498C>T p.S166= | Silent (SNP) | VAF 22/57 reads (39%) | catalogued as rs141170715; called by muse, mutect2, varscan2
- NUGGC | c.723G>A p.L241= | Silent (SNP) | VAF 18/64 reads (28%) | catalogued as COSV100429915; called by muse, mutect2, varscan2
- ORAI3 | c.366C>T p.H122= | Silent (SNP) | VAF 4/30 reads (13%) | catalogued as COSV52690175; called by muse, mutect2
- PAF1 | c.1431C>T p.G477= | Silent (SNP) | VAF 15/44 reads (34%) | catalogued as COSV99656127; called by muse, mutect2, varscan2
- PATJ | c.876C>T p.H292= | Silent (SNP) | VAF 23/59 reads (39%) | catalogued as COSV100335270; called by muse, mutect2, varscan2
- PC | c.3267C>T p.V1089= | Silent (SNP) | VAF 10/24 reads (42%) | catalogued as rs746903912, COSV100547207; called by muse, mutect2, varscan2
- PC | c.345C>T p.H115= | Silent (SNP) | VAF 10/27 reads (37%) | catalogued as COSV100852363; called by muse, mutect2, varscan2
- PCDHA2 | c.825C>T p.S275= | Silent (SNP) | VAF 8/14 reads (57%) | catalogued as rs782729838, COSV100973462; called by muse, mutect2, varscan2
- PCDHA6 | c.1509G>A p.A503= | Silent (SNP) | VAF 47/105 reads (45%) | catalogued as rs782636374, COSV100971740, COSV65343482; called by muse, mutect2, varscan2
- PCDHA6 | c.1929G>A p.P643= | Silent (SNP) | VAF 7/87 reads (8%) | catalogued as rs782361791, COSV65342222; called by muse, mutect2
- PCDHGA3 | c.1794G>A p.S598= | Silent (SNP) | VAF 26/94 reads (28%) | catalogued as rs779769007, COSV99549411; called by muse, mutect2, varscan2
- PIDD1 | c.1192C>T p.L398= | Silent (SNP) | VAF 6/38 reads (16%) | catalogued as COSV100758833; called by muse, mutect2, varscan2
- PITPNM1 | c.2808C>T p.S936= | Silent (SNP) | VAF 21/49 reads (43%) | catalogued as rs756646211, COSV99653924; called by muse, mutect2, varscan2
- PKD1 | c.1359G>A p.Q453= | Silent (SNP) | VAF 41/85 reads (48%) | catalogued as COSV99239309; called by muse, mutect2, varscan2
- PLCB3 | c.1812C>A p.S604= | Silent (SNP) | VAF 23/56 reads (41%) | catalogued as rs199625600, COSV99657857; called by muse, mutect2, varscan2
- PNKD | c.424C>T p.L142= | Silent (SNP) | VAF 15/50 reads (30%) | catalogued as COSV99282727; called by muse, mutect2, varscan2
- PRTG | c.3168C>T p.F1056= | Silent (SNP) | VAF 6/33 reads (18%) | called by muse, mutect2, varscan2
- PSD2 | c.519C>T p.C173= | Silent (SNP) | VAF 9/53 reads (17%) | catalogued as rs529058855, COSV51198522; called by muse, mutect2, varscan2
- PTPN21 | c.1656C>T p.Y552= | Silent (SNP) | VAF 7/14 reads (50%) | catalogued as rs1418199859, COSV100162665; called by muse, mutect2, varscan2
- PYCR2 | c.255C>T p.D85= | Silent (SNP) | VAF 6/45 reads (13%) | catalogued as rs768872418, COSV100661584; called by muse, mutect2, varscan2
- RARA | c.84C>T p.F28= | Silent (SNP) | VAF 4/18 reads (22%) | catalogued as COSV99565582; called by muse, mutect2
- RHBDD3 | c.543G>T p.G181= | Silent (SNP) | VAF 4/12 reads (33%) | catalogued as COSV99328661; called by mutect2, varscan2
- RIMS2 | c.315C>T p.G105= | Silent (SNP) | VAF 10/62 reads (16%) | catalogued as rs1424242926, COSV101345148; called by muse, mutect2, varscan2
- RNF31 | c.2292C>A p.T764= | Silent (SNP) | VAF 4/48 reads (8%) | catalogued as COSV100142154; called by muse, mutect2
- RREB1 | c.4740G>T p.R1580= | Silent (SNP) | VAF 7/26 reads (27%) | catalogued as COSV100619962; called by muse, mutect2, varscan2
- RTL5 | c.774T>C p.F258= | Silent (SNP) | VAF 31/56 reads (55%) | catalogued as COSV101030424; called by muse, mutect2, varscan2
- SALL3 | c.267G>A p.P89= | Silent (SNP) | VAF 7/19 reads (37%) | catalogued as COSV73305722; called by muse, mutect2
- SCUBE2 | c.216C>A p.S72= | Silent (SNP) | VAF 11/93 reads (12%) | catalogued as COSV100497056; called by muse, mutect2, varscan2
- SEC23B | c.1455G>A p.T485= | Silent (SNP) | VAF 10/30 reads (33%) | catalogued as rs553661024, COSV52723139; called by muse, mutect2, varscan2
- SEMA3A | c.987G>A p.T329= | Silent (SNP) | VAF 26/64 reads (41%) | catalogued as rs139214465, COSV54886278; called by muse, mutect2, varscan2
- SEMA6B | c.954C>G p.P318= | Silent (SNP) | VAF 21/42 reads (50%) | catalogued as rs763428054, COSV100015244; called by muse, mutect2, varscan2
- SLC24A3 | c.1644C>T p.S548= | Silent (SNP) | VAF 28/59 reads (47%) | catalogued as COSV100043534; called by muse, mutect2, varscan2
- SLC35B3 | c.678G>A p.L226= | Silent (SNP) | VAF 21/60 reads (35%) | catalogued as rs1400270051, COSV100217444; called by muse, mutect2, varscan2
- SLC44A2 | c.1327C>T p.L443= | Silent (SNP) | VAF 36/75 reads (48%) | catalogued as COSV59836987; called by muse, mutect2, varscan2
- SLC9A5 | c.238C>T p.L80= | Silent (SNP) | VAF 23/64 reads (36%) | catalogued as COSV99264642; called by muse, mutect2, varscan2
- SLTM | c.3093G>A p.P1031= | Silent (SNP) | VAF 24/47 reads (51%) | catalogued as rs199687843; called by muse, mutect2, varscan2
- SMG1 | c.1062T>C p.L354= | Silent (SNP) | VAF 23/173 reads (13%) | catalogued as COSV101247012; called by muse, mutect2, varscan2
- SPAG16 | c.1158G>A p.V386= | Silent (SNP) | VAF 16/46 reads (35%) | catalogued as COSV100536647; called by muse, mutect2, varscan2
- SPATA2 | c.84T>C p.D28= | Silent (SNP) | VAF 30/84 reads (36%) | catalogued as rs773964657, COSV99193027; called by muse, mutect2, varscan2
- SPPL2C | c.1818C>T p.D606= | Silent (SNP) | VAF 7/23 reads (30%) | catalogued as rs374530875; called by muse, mutect2, varscan2
- SPTB | c.6324G>A p.A2108= | Silent (SNP) | VAF 19/41 reads (46%) | catalogued as rs756164746, COSV100731212; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SPTBN2 | c.3192G>A p.A1064= | Silent (SNP) | VAF 4/17 reads (24%) | catalogued as rs371684236; called by muse, mutect2, varscan2
- SSBP2 | c.651T>C p.G217= | Silent (SNP) | VAF 18/68 reads (26%) | catalogued as COSV57799201; called by muse, mutect2, varscan2
- STARD13 | c.210C>T p.A70= | Silent (SNP) | VAF 12/16 reads (75%) | catalogued as rs749218590, COSV99716516; called by muse, varscan2
- STAT1 | c.691C>T p.L231= | Silent (SNP) | VAF 10/18 reads (56%) | catalogued as COSV100700027; called by muse, mutect2, varscan2
- STX11 | c.105C>T p.F35= | Silent (SNP) | VAF 8/33 reads (24%) | catalogued as rs770690889, COSV62448694; called by muse, mutect2, varscan2
- SUPT16H | c.393C>T p.G131= | Silent (SNP) | VAF 30/91 reads (33%) | catalogued as COSV99360304; called by muse, mutect2, varscan2
- TBC1D8 | c.3165T>C p.P1055= | Silent (SNP) | VAF 20/32 reads (63%) | catalogued as COSV99961624; called by muse, mutect2
- TENT5A | c.840T>C p.I280= | Silent (SNP) | VAF 22/61 reads (36%) | catalogued as COSV100199227; called by muse, mutect2, varscan2
- TESMIN | c.168G>A p.P56= | Silent (SNP) | VAF 16/30 reads (53%) | catalogued as rs1298323379, COSV99664084; called by muse, mutect2, varscan2
- TFIP11 | c.891G>A p.P297= | Silent (SNP) | VAF 20/46 reads (43%) | catalogued as rs752593742, COSV53228246; called by muse, mutect2, varscan2
- TMEM70 | c.282A>G p.L94= | Silent (SNP) | VAF 19/62 reads (31%) | catalogued as COSV100384215; called by muse, mutect2, varscan2
- TOB2 | c.585C>T p.G195= | Silent (SNP) | VAF 4/13 reads (31%) | catalogued as rs375176426; called by muse, mutect2, varscan2
- TPCN2 | c.531T>C p.S177= | Silent (SNP) | VAF 37/91 reads (41%) | catalogued as COSV99594069; called by muse, mutect2, varscan2
- TRAF5 | c.1260G>A p.A420= | Silent (SNP) | VAF 14/44 reads (32%) | catalogued as rs781186642, COSV99807700; called by muse, mutect2, varscan2
- TRIM28 | c.2100C>T p.N700= | Silent (SNP) | VAF 25/61 reads (41%) | catalogued as COSV99449559; called by muse, mutect2, varscan2
- TRIOBP | c.3393G>A p.E1131= | Silent (SNP) | VAF 17/35 reads (49%) | catalogued as COSV100731203; called by muse, mutect2, varscan2
- TRPV1 | c.195C>T p.H65= | Silent (SNP) | VAF 19/49 reads (39%) | catalogued as rs201702963, COSV51526057, COSV99440970; called by muse, mutect2, varscan2
- TTN | c.3243G>A p.A1081= (on ENST00000591111; = p.A1035= on NM_003319.4) | Silent (SNP) | VAF 14/38 reads (37%) | catalogued as rs559501661, COSV60327336; called by muse, mutect2, varscan2
- VARS1 | c.3636G>A p.Q1212= | Silent (SNP) | VAF 12/23 reads (52%) | catalogued as COSV100791873; called by muse, mutect2, varscan2
- VMP1 | c.1068C>T p.G356= | Silent (SNP) | VAF 14/46 reads (30%) | catalogued as rs1239896293, COSV99231123; called by muse, mutect2, varscan2
- WDFY3 | c.6619C>T p.L2207= | Silent (SNP) | VAF 14/26 reads (54%) | catalogued as COSV99886332; called by muse, mutect2, varscan2
- WRN | c.2517C>T p.Y839= | Silent (SNP) | VAF 7/21 reads (33%) | catalogued as rs779314628, COSV53300020; ClinVar: likely benign; called by muse, mutect2, varscan2
- ZC3H12A | c.645C>T p.R215= | Silent (SNP) | VAF 16/37 reads (43%) | catalogued as COSV66103854; called by muse, mutect2, varscan2
- ZCCHC24 | c.273C>T p.G91= | Silent (SNP) | VAF 9/17 reads (53%) | catalogued as rs138062570; called by muse, mutect2, varscan2
- ZNF232 | c.1323G>A p.E441= | Silent (SNP) | VAF 11/26 reads (42%) | catalogued as rs147321283; called by muse, mutect2, varscan2
- ZNF275 | c.801C>T p.C267= | Silent (SNP) | VAF 7/22 reads (32%) | catalogued as rs373432812, COSV100936489; called by muse, mutect2, varscan2
- ZNF680 | c.636T>C p.C212= | Silent (SNP) | VAF 13/40 reads (33%) | catalogued as COSV100549378; called by muse, mutect2, varscan2
- ZNF764 | c.1017C>T p.G339= | Silent (SNP) | VAF 9/18 reads (50%) | catalogued as rs755194300, COSV99411249; called by muse, varscan2
- ACAA2 | chr18:49814125 C>A | 5'Flank (SNP) | VAF 22/46 reads (48%) | called by muse, mutect2, varscan2
- AK9 | c.3633+13_3633+16del | Intron (DEL) | VAF 16/50 reads (32%) | catalogued as rs766264675; called by pindel, varscan2
- AL161729.4 | chr9:95516662 T>C | 3'Flank (SNP) | VAF 20/73 reads (27%) | catalogued as COSV100934394; called by muse, mutect2, varscan2
- AL353804.7 | chrX:73852595 del T | 3'Flank (DEL) | VAF 4/16 reads (25%) | called by mutect2, varscan2
- C5orf64 | n.512+51971del | Intron (DEL) | VAF 4/34 reads (12%) | called by pindel, varscan2
- CEP295 | c.5851-193del | Intron (DEL) | VAF 8/46 reads (17%) | catalogued as rs754124024; called by mutect2, pindel, varscan2
- COL6A2 | c.2462-2696G>A | Intron (SNP) | VAF 7/36 reads (19%) | catalogued as rs761176289, COSV56012000; called by muse, mutect2, varscan2
- FOLH1B | n.1799dup | RNA (INS) | VAF 5/26 reads (19%) | called by mutect2, pindel, varscan2
- IGLL5 | chr22:22899649 G>A | 3'Flank (SNP) | VAF 31/95 reads (33%) | catalogued as rs763649871; called by muse, mutect2, varscan2
- KIF1B | c.2115+6691C>T | Intron (SNP) | VAF 11/20 reads (55%) | catalogued as rs1378385943, COSV99822528, COSV99824460; called by muse, mutect2, varscan2
- LINC00482 | n.477G>A | RNA (SNP) | VAF 7/12 reads (58%) | called by muse, mutect2, varscan2
- MIR421 | n.53C>A | RNA (SNP) | VAF 15/35 reads (43%) | called by muse, mutect2, varscan2
- MYL3 | chr3:46834009 C>T | 3'Flank (SNP) | VAF 8/34 reads (24%) | catalogued as rs767561504, COSV101451286; called by muse, mutect2
- RN7SL484P | chr15:99790776 C>T | 5'Flank (SNP) | VAF 4/13 reads (31%) | catalogued as rs1333099521; called by mutect2, varscan2
- SGIP1 | c.99+999del | Intron (DEL) | VAF 6/38 reads (16%) | catalogued as rs745636084, COSV52764888; called by mutect2, varscan2
- SSX9P | n.123A>G | RNA (SNP) | VAF 14/192 reads (7%) | called by muse, mutect2
